Somatic mutation profile of cancer-model specimen HCM-WCMC-0789-C34-85A (3D Organoid, passage 11; aliquot HCM-WCMC-0789-C34-85A-01D-A87L-36), derived from the primary tumor of HCMI case HCM-WCMC-0789-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA2; Tumor grade: G2; Age at diagnosis: 83.6 years (30,550 days).
Specimen HCM-WCMC-0789-C34-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Cryopreserved; Passage count: 11.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c69b1df2-4e03-4157-80ab-ebc8d632049e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0789-C34-10A (Blood Derived Normal), aliquot HCM-WCMC-0789-C34-10A-01D-A87L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5a9c7b75-1cc6-4a87-850e-dc0e7871f9f9

The open-access MAF lists 813 somatic variants for this specimen: 588 protein-altering or splice-affecting, 208 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 525, Silent 208, Nonsense Mutation 47, Intron 8, Frame Shift Del 7, Splice Region 4, 5'UTR 3, Nonstop Mutation 3, 3'UTR 3, Splice Site 2, 5'Flank 2, 3'Flank 1.

Variants (750 of 813; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 102/237 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABHD3 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 21/367 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as COSV56676289, COSV56677493, COSV56678649; called by muse, mutect2
- ACIN1 | c.26C>T p.T9I | Missense Mutation (SNP) | VAF 148/322 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs769850217; called by muse, mutect2, varscan2
- ACTR10 | c.385C>G p.L129V | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.334); catalogued as COSV54298791; called by muse, mutect2
- ADAMTSL3 | c.4454C>G p.A1485G | Missense Mutation (SNP) | VAF 139/216 reads (64%) | SIFT tolerated (0.32); PolyPhen benign (0.149); catalogued as rs750268074, COSV54471471; called by muse, mutect2, varscan2
- ADCK1 | c.553C>T p.Q185* | Nonsense Mutation (SNP) | VAF 106/256 reads (41%) | catalogued as rs1479461067; called by muse, mutect2, varscan2
- ADGRB2 | c.2191G>A p.V731I | Missense Mutation (SNP) | VAF 113/286 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs1428081976; called by muse, mutect2, varscan2
- ADGRE1 | c.693C>G p.I231M | Missense Mutation (SNP) | VAF 107/275 reads (39%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.51); catalogued as COSV51679163; called by muse, mutect2, varscan2
- ADGRL3 | c.2498G>A p.G833E (on ENST00000506720 / NM_001322402.2; = p.G765E on NM_015236.6) | Missense Mutation (SNP) | VAF 184/405 reads (45%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.925); catalogued as rs557402887; called by muse, mutect2, varscan2
- AGPAT1 | c.613A>G p.I205V | Missense Mutation (SNP) | VAF 175/386 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.371); catalogued as rs767772319; called by muse, mutect2, varscan2
- ANK3 | c.225G>C p.L75F | Missense Mutation (SNP) | VAF 16/219 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55042273; called by muse, mutect2
- AP3D1 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 33/401 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs769763871; called by muse, mutect2
- APLF | c.1030C>T p.H344Y | Missense Mutation (SNP) | VAF 38/442 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.36); catalogued as rs763741027; called by muse, mutect2
- ATG4D | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 61/327 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs771104951; called by muse, mutect2, varscan2
- ATP1A2 | c.659C>T p.S220L | Missense Mutation (SNP) | VAF 20/743 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as CM139985, COSV63403248; called by muse, mutect2
- ATP4A | c.397G>T p.G133W | Missense Mutation (SNP) | VAF 16/366 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); catalogued as COSV99382994; called by muse, mutect2
- BCL2L11 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 212/647 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs777425286; called by muse, mutect2, varscan2
- BCORL1 | c.4802C>G p.S1601* | Nonsense Mutation (SNP) | VAF 156/205 reads (76%) | catalogued as rs1167330881, COSV99499831; called by muse, mutect2, varscan2
- BRAT1 | c.2370G>T p.E790D | Missense Mutation (SNP) | VAF 155/258 reads (60%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs759592506, COSV61395182; called by muse, mutect2, varscan2
- C12orf40 | c.23+1del | Frame Shift Del (DEL) | VAF 146/342 reads (43%) | catalogued as COSV61132520; called by mutect2, pindel, varscan2
- C16orf87 | c.13C>T p.R5* | Nonsense Mutation (SNP) | VAF 122/266 reads (46%) | catalogued as rs754738913, COSV99587569; called by muse, mutect2, varscan2
- CAMK2G | c.706C>G p.P236A | Missense Mutation (SNP) | VAF 132/242 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs1279584071; called by muse, mutect2, varscan2
- CAND2 | c.2750C>G p.S917* (on ENST00000456430 / NM_001162499.2; = p.S824* on NM_012298.3) | Nonsense Mutation (SNP) | VAF 239/479 reads (50%) | catalogued as COSV55990716; called by muse, mutect2, varscan2
- CAPN14 | c.57G>T p.R19S | Missense Mutation (SNP) | VAF 192/555 reads (35%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV67290255; called by muse, mutect2, varscan2
- CCDC154 | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 135/308 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs561677923, COSV101209693, COSV101209706; called by muse, mutect2, varscan2
- CCDC171 | c.562C>G p.Q188E | Missense Mutation (SNP) | VAF 100/260 reads (38%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.001); catalogued as COSV99899603; called by muse, mutect2, varscan2
- CCDC178 | c.1375G>C p.D459H | Missense Mutation (SNP) | VAF 64/171 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1568101484, COSV55767077; called by muse, mutect2, varscan2
- CDC14B | c.1430G>C p.R477T | Missense Mutation (SNP) | VAF 32/340 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as COSV55785655; called by muse, mutect2
- CDC42BPG | c.3051C>G p.I1017M | Missense Mutation (SNP) | VAF 26/199 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61346793; called by muse, mutect2, varscan2
- CDKL4 | c.807G>A p.M269I | Missense Mutation (SNP) | VAF 96/305 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.348); catalogued as COSV101115558; called by muse, mutect2, varscan2
- CEP120 | c.2695G>C p.E899Q | Missense Mutation (SNP) | VAF 95/381 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV60264300; called by muse, mutect2, varscan2
- CHD1 | c.1936C>G p.L646V | Missense Mutation (SNP) | VAF 18/433 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52339160; called by muse, mutect2
- CHEK2 | c.1378C>G p.L460V (on ENST00000382580 / NM_001005735.2; = p.L417V on NM_007194.4) | Missense Mutation (SNP) | VAF 144/238 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100101286; called by muse, varscan2
- CMKLR1 | c.379G>A p.V127I (on ENST00000312143 / NM_001142344.2; = p.V125I on NM_004072.3) | Missense Mutation (SNP) | VAF 171/335 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); catalogued as rs374487323; called by muse, mutect2, varscan2
- CNTNAP5 | c.3644C>T p.S1215F | Missense Mutation (SNP) | VAF 15/272 reads (6%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.96); catalogued as COSV70473997; called by muse, mutect2
- COL28A1 | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 71/590 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs756862861; called by muse, mutect2, varscan2
- CPS1 | c.1391C>A p.P464Q | Missense Mutation (SNP) | VAF 105/338 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51826143; called by mutect2, varscan2
- CSMD1 | c.9483C>G p.I3161M (on ENST00000520002; = p.I3160M on NM_033225.6) | Missense Mutation (SNP) | VAF 222/343 reads (65%) | SIFT tolerated (0.2); PolyPhen benign (0.266); catalogued as COSV59327086; called by muse, mutect2
- CUEDC1 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 53/383 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs369323259; called by muse, mutect2, varscan2
- CUL5 | c.2107G>C p.E703Q | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV101263745; called by muse, mutect2
- CYP2A13 | c.436G>T p.E146* | Nonsense Mutation (SNP) | VAF 157/368 reads (43%) | catalogued as rs201720562; called by muse, mutect2, varscan2
- DAO | c.794G>A p.R265K | Missense Mutation (SNP) | VAF 31/306 reads (10%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV57324445; called by muse, mutect2
- DBX1 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 26/386 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs866316035, COSV57055507; called by muse, mutect2
- DCLRE1B | c.1516C>G p.L506V | Missense Mutation (SNP) | VAF 27/393 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV65813256; called by muse, mutect2
- DDI2 | c.418G>C p.D140H | Missense Mutation (SNP) | VAF 32/350 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV100197669; called by muse, mutect2
- DDX23 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 167/387 reads (43%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.899); catalogued as rs1158425469; called by muse, mutect2, varscan2
- DDX27 | c.2079G>C p.E693D | Missense Mutation (SNP) | VAF 58/302 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs754093153, COSV65595189; called by muse, mutect2, varscan2
- DDX3X | c.982G>C p.D328H (on ENST00000399959; = p.D329H on NM_001356.5) | Missense Mutation (SNP) | VAF 17/165 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101302320, COSV101302559; called by muse, mutect2, varscan2
- DDX4 | c.1099G>C p.E367Q | Missense Mutation (SNP) | VAF 140/428 reads (33%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.615); catalogued as COSV61757771; called by muse, mutect2, varscan2
- DEPDC7 | c.1519G>A p.E507K (on ENST00000241051 / NM_001077242.2; = p.E498K on NM_139160.2) | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as rs775479621; called by muse, mutect2, varscan2
- DIO3 | c.349G>T p.V117L | Missense Mutation (SNP) | VAF 227/471 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV63773899; called by muse, mutect2, varscan2
- DIS3 | c.1463A>T p.D488V | Missense Mutation (SNP) | VAF 18/298 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66706118, COSV66708289; called by muse, mutect2
- DMP1 | c.819C>G p.I273M | Missense Mutation (SNP) | VAF 22/362 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs968385548; called by muse, mutect2
- DNAH1 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 20/508 reads (4%) | SIFT tolerated (0.62); PolyPhen benign (0.058); catalogued as COSV101324979; called by muse, mutect2
- DNAH14 | c.622G>A p.E208K (on ENST00000445597; = p.E31K on NM_144989.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/375 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV64781336; called by muse, mutect2, varscan2
- DNAH3 | c.4942C>G p.L1648V | Missense Mutation (SNP) | VAF 15/268 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99766652; called by muse, mutect2
- DNAH6 | c.12326G>A p.C4109Y | Missense Mutation (SNP) | VAF 137/479 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV52849241; called by muse, mutect2, varscan2
- EDN2 | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 26/446 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758555144, COSV65423359; called by muse, mutect2
- ELAPOR1 | c.1927C>T p.P643S | Missense Mutation (SNP) | VAF 140/258 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as COSV64041099; called by muse, mutect2, varscan2
- ELL3 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 12/326 reads (4%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.998); catalogued as COSV55854486, COSV55855508; called by muse, mutect2
- ELOA | c.905C>G p.S302C | Missense Mutation (SNP) | VAF 57/316 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV69310677; called by muse, mutect2, varscan2
- EML2 | c.509C>G p.S170C | Missense Mutation (SNP) | VAF 77/157 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs746457264; called by muse, mutect2, varscan2
- EMP2 | c.227G>T p.C76F | Missense Mutation (SNP) | VAF 176/386 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.489); catalogued as COSV63995963; called by muse, mutect2
- ENG | c.1678C>G p.Q560E | Missense Mutation (SNP) | VAF 106/231 reads (46%) | SIFT tolerated (0.62); PolyPhen benign (0.149); catalogued as CM050586, COSV100785268; called by muse, mutect2, varscan2
- EPHB6 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 281/620 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as rs1045338681, COSV67420772; called by muse, mutect2, varscan2
- ETV6 | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 14/415 reads (3%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.779); catalogued as COSV101122480; called by muse, mutect2
- EXPH5 | c.2045C>T p.S682F | Missense Mutation (SNP) | VAF 142/324 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); catalogued as COSV56198909; called by muse, mutect2
- FAM160B1 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 67/327 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0.254); catalogued as COSV65088918; called by muse, mutect2, varscan2
- FBN2 | c.8114C>A p.P2705H | Missense Mutation (SNP) | VAF 288/457 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52539840; called by muse, mutect2, varscan2
- FCER1A | c.280C>A p.Q94K | Missense Mutation (SNP) | VAF 28/573 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV63666484; called by muse, mutect2
- FGD5 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 20/530 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV53255520; called by muse, mutect2
- FNBP1 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 32/328 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV63089965; called by muse, mutect2
- FZD10 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 186/485 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as rs1177476271; called by muse, mutect2, varscan2
- GABRA3 | c.1468C>A p.R490S | Missense Mutation (SNP) | VAF 150/150 reads (100%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.066); catalogued as COSV64794720; called by muse, mutect2, varscan2
- GALNT2 | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 48/974 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as COSV100795623; called by muse, mutect2
- GCM1 | c.58G>T p.D20Y | Missense Mutation (SNP) | VAF 15/274 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52522435; called by muse, mutect2
- GCNT1 | c.1219G>T p.D407Y | Missense Mutation (SNP) | VAF 82/294 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65056994; called by muse, mutect2, varscan2
- GLB1 | c.1997C>T p.P666L | Missense Mutation (SNP) | VAF 109/206 reads (53%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.859); catalogued as rs754538192, COSV56563660; called by muse, mutect2, varscan2
- GNB3 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 100/296 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV51831081; called by muse, mutect2, varscan2
- GNB5 | c.150G>C p.E50D (on ENST00000261837 / NM_016194.4; = p.E8D on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/353 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs991564773; called by muse, mutect2
- GPR107 | c.1208C>A p.S403Y | Missense Mutation (SNP) | VAF 19/365 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1448896871; called by muse, mutect2
- GPR137 | c.1247C>T p.S416F | Missense Mutation (SNP) | VAF 24/374 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs775046189; called by muse, mutect2
- GRIK5 | c.1315G>T p.G439W | Missense Mutation (SNP) | VAF 159/362 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99489937; called by muse, mutect2, varscan2
- GRM2 | c.44G>A p.G15D | Missense Mutation (SNP) | VAF 149/322 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as rs1365229369; called by muse, mutect2, varscan2
- GTF2IRD1 | c.2703G>C p.K901N (on ENST00000265755 / NM_016328.3; = p.K886N on NM_005685.4) | Missense Mutation (SNP) | VAF 14/428 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs782329453, COSV56085109; called by muse, mutect2
- HERC6 | c.2362C>G p.L788V | Missense Mutation (SNP) | VAF 14/335 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99986584; called by muse, mutect2
- HOXA6 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 100/482 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.153); catalogued as COSV56071920; called by muse, mutect2, varscan2
- HRNR | c.1548C>G p.S516R | Missense Mutation (SNP) | VAF 148/316 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.154); catalogued as COSV64259774; called by muse, mutect2
- IARS2 | c.1606C>A p.H536N | Missense Mutation (SNP) | VAF 84/609 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as rs1299955084, COSV56964315; called by muse, mutect2, varscan2
- IER3 | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 187/368 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs1489268996; called by muse, mutect2, varscan2
- IGFBP2 | c.577G>T p.E193* | Nonsense Mutation (SNP) | VAF 336/530 reads (63%) | catalogued as COSV52080535; called by muse, mutect2, varscan2
- IGHV2-5 | c.272C>A p.T91N | Missense Mutation (SNP) | VAF 206/388 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as rs782068483; called by muse, mutect2
- IGHV4-39 | c.326A>G p.K109R | Missense Mutation (SNP) | VAF 115/310 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs757102271; called by muse, varscan2
- IL33 | c.289G>A p.G97S | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs1191838292; called by muse, mutect2
- IRF6 | c.104G>T p.R35L | Missense Mutation (SNP) | VAF 351/525 reads (67%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as CM092321, COSV65419083; called by muse, mutect2, varscan2
- ITK | c.36C>G p.I12M | Missense Mutation (SNP) | VAF 125/466 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs751083005; called by muse, mutect2, varscan2
- ITPRIPL1 | c.295G>A p.D99N (on ENST00000439118 / NM_001008949.3; = p.D107N on NM_178495.6) | Missense Mutation (SNP) | VAF 129/404 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs369211145; called by muse, mutect2, varscan2
- KCNH5 | c.155G>T p.G52V | Missense Mutation (SNP) | VAF 92/208 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59757775; called by mutect2, varscan2
- KCNK2 | c.22G>T p.E8* | Nonsense Mutation (SNP) | VAF 151/664 reads (23%) | catalogued as rs765168645; called by muse, mutect2, varscan2
- KCNMA1 | c.1384C>T p.Q462* | Nonsense Mutation (SNP) | VAF 25/384 reads (7%) | catalogued as COSV54290064; called by muse, mutect2
- KDM5B | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 76/273 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV99351025; called by muse, mutect2, varscan2
- KEAP1 | c.1475C>G p.P492R | Missense Mutation (SNP) | VAF 154/346 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99408188; called by muse, varscan2
- KIAA1210 | c.1478G>A p.S493N | Missense Mutation (SNP) | VAF 114/114 reads (100%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV68178274; called by mutect2, varscan2
- KIF4B | c.114G>T p.E38D | Missense Mutation (SNP) | VAF 417/597 reads (70%) | SIFT deleterious (0.03); PolyPhen benign (0.155); catalogued as COSV70531618; called by muse, mutect2, varscan2
- KLLN | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 190/360 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as rs962216778, COSV64288439; called by muse, mutect2, varscan2
- KMT2E | c.794C>T p.S265L | Missense Mutation (SNP) | VAF 18/237 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.164); catalogued as COSV57570453, COSV57580643; called by muse, mutect2
- KRT9 | c.787G>T p.V263L | Missense Mutation (SNP) | VAF 180/398 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.069); catalogued as rs1218831432; called by muse, mutect2, varscan2
- LAMC1 | c.891G>C p.K297N | Missense Mutation (SNP) | VAF 24/584 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.395); catalogued as COSV99278733; called by muse, mutect2
- LHX8 | c.623G>T p.S208I | Missense Mutation (SNP) | VAF 92/180 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as rs753429679, COSV53955348; called by muse, mutect2, varscan2
- LMOD3 | c.649G>C p.D217H | Missense Mutation (SNP) | VAF 157/333 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV70455935; called by muse, mutect2, varscan2
- LRBA | c.7025C>T p.S2342L | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63964872; called by muse, mutect2
- LRFN1 | c.1174C>G p.L392V | Missense Mutation (SNP) | VAF 14/450 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0.379); catalogued as COSV50450890; called by muse, mutect2
- LRRN4CL | c.367G>C p.E123Q | Missense Mutation (SNP) | VAF 149/485 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.072); catalogued as COSV99042307; called by muse, mutect2, varscan2
- LTN1 | c.1470C>G p.F490L | Missense Mutation (SNP) | VAF 140/468 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as COSV63734606; called by muse, mutect2, varscan2
- MAGEC1 | c.1681C>G p.P561A | Missense Mutation (SNP) | VAF 204/290 reads (70%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.956); catalogued as COSV53579808; called by muse, mutect2, varscan2
- MASP1 | c.2003G>C p.W668S | Missense Mutation (SNP) | VAF 29/457 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1236886356, COSV61824127; called by muse, mutect2
- MAST4 | c.6050C>G p.S2017C (on ENST00000403625 / NM_001164664.2; = p.S1828C on NM_015183.3) | Missense Mutation (SNP) | VAF 155/647 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.047); catalogued as COSV55123944; called by muse, mutect2, varscan2
- MB21D2 | c.931C>T p.Q311* | Nonsense Mutation (SNP) | VAF 39/249 reads (16%) | catalogued as COSV66661548, COSV66661553; called by muse, mutect2, varscan2
- MCTP1 | c.2014G>C p.E672Q | Missense Mutation (SNP) | VAF 110/336 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs752810491; called by muse, mutect2, varscan2
- METTL25 | c.78C>A p.F26L | Missense Mutation (SNP) | VAF 16/366 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99810782; called by muse, mutect2
- MSI1 | c.176G>A p.R59K | Missense Mutation (SNP) | VAF 18/404 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as rs1206220387; called by muse, mutect2
- MYCBP2 | c.8043C>G p.I2681M (on ENST00000357337; = p.I2719M on NM_015057.5) | Missense Mutation (SNP) | VAF 8/254 reads (3%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV62020238; called by muse, mutect2
- N4BP1 | c.734C>A p.S245Y | Missense Mutation (SNP) | VAF 16/374 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV99284970; called by muse, mutect2
- NAALADL1 | c.1009G>A p.V337I | Missense Mutation (SNP) | VAF 144/336 reads (43%) | SIFT tolerated (0.79); PolyPhen benign (0.067); catalogued as rs1277436890; called by muse, mutect2, varscan2
- NAIF1 | c.188G>C p.R63T | Missense Mutation (SNP) | VAF 16/492 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66092929; called by muse, mutect2
- NBAS | c.1016C>T p.S339L | Missense Mutation (SNP) | VAF 82/318 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV55720442; called by muse, mutect2, varscan2
- NBN | c.638C>G p.S213* | Nonsense Mutation (SNP) | VAF 14/231 reads (6%) | catalogued as COSV55371345; called by muse, mutect2
- NCCRP1 | c.620C>T p.T207M | Missense Mutation (SNP) | VAF 251/479 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs147663476, COSV59212772; called by muse, mutect2, varscan2
- NCKAP1L | c.2305G>T p.A769S | Missense Mutation (SNP) | VAF 189/367 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV53210503; called by muse, mutect2, varscan2
- NCOA6 | c.1559C>T p.S520L | Missense Mutation (SNP) | VAF 27/291 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as COSV100750293; called by muse, mutect2
- NEIL3 | c.1168C>G p.L390V | Missense Mutation (SNP) | VAF 13/312 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV99221005; called by muse, mutect2
- NEUROD4 | c.613C>G p.Q205E | Missense Mutation (SNP) | VAF 177/420 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.796); catalogued as COSV54471013; called by muse, mutect2, varscan2
- NF1 | c.7213A>G p.I2405V (on ENST00000358273 / NM_001042492.3; = p.I2384V on NM_000267.3) | Missense Mutation (SNP) | VAF 69/262 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs565708398, COSV62194004; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRP2 | c.2676G>C p.L892F | Missense Mutation (SNP) | VAF 14/410 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs922105657; called by muse, mutect2
- NPY1R | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as COSV99648805; called by muse, mutect2
- NRG3 | c.118G>A p.G40S | Missense Mutation (SNP) | VAF 144/236 reads (61%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs1443700215; called by muse, varscan2
- NUP93 | c.43C>G p.Q15E | Missense Mutation (SNP) | VAF 25/282 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV57428872, COSV57434100; called by muse, mutect2
- OR4C12 | c.146C>T p.T49I | Missense Mutation (SNP) | VAF 50/263 reads (19%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); catalogued as rs1555020318; called by muse, mutect2, varscan2
- OR4K17 | c.906G>C p.W302C | Missense Mutation (SNP) | VAF 52/113 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100210695; called by muse, mutect2, varscan2
- OR51B2 | c.508C>G p.H170D | Missense Mutation (SNP) | VAF 118/241 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV60916027; called by muse, mutect2, varscan2
- PALLD | c.2394G>A p.M798I (on ENST00000505667 / NM_001166108.2; = p.M781I on NM_016081.4) | Missense Mutation (SNP) | VAF 29/413 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs867880065; called by muse, mutect2
- PCDH18 | c.215G>T p.G72V | Missense Mutation (SNP) | VAF 173/336 reads (51%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV61266672, COSV61268906; called by muse, mutect2, varscan2
- PCDH18 | c.214G>T p.G72* | Nonsense Mutation (SNP) | VAF 167/320 reads (52%) | catalogued as COSV61270126; called by mutect2, varscan2
- PDE2A | c.72-3C>T | Splice Region (SNP) | VAF 71/303 reads (23%) | catalogued as rs1343631982; called by muse, varscan2
- PEX1 | c.1182G>C p.L394F | Missense Mutation (SNP) | VAF 36/233 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV99952313; called by muse, mutect2, varscan2
- PHACTR2 | c.1018C>T p.L340F | Missense Mutation (SNP) | VAF 19/458 reads (4%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.146); catalogued as rs893198888; called by muse, mutect2
- PHKB | c.1889G>T p.R630L | Missense Mutation (SNP) | VAF 75/196 reads (38%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.84); catalogued as COSV54515097; called by muse, mutect2, varscan2
- PHLPP2 | c.1843G>A p.G615R | Missense Mutation (SNP) | VAF 29/394 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.373); catalogued as COSV100673570; called by muse, mutect2
- PIKFYVE | c.379C>T p.Q127* | Nonsense Mutation (SNP) | VAF 109/382 reads (29%) | catalogued as COSV52248375; called by muse, mutect2, varscan2
- PITPNM1 | c.836G>T p.R279L | Missense Mutation (SNP) | VAF 283/524 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as COSV62708361; called by muse, mutect2, varscan2
- PJA1 | c.770G>T p.R257M | Missense Mutation (SNP) | VAF 199/199 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64053589; called by muse, mutect2, varscan2
- PLEKHG4 | c.1594C>G p.L532V | Missense Mutation (SNP) | VAF 150/389 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.097); catalogued as rs145759648; called by muse, mutect2, varscan2
- PLPPR3 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 16/382 reads (4%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.679); catalogued as COSV62461246; called by muse, mutect2
- PNISR | c.270G>C p.W90C | Missense Mutation (SNP) | VAF 125/238 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1043533000; called by muse, mutect2, varscan2
- POU2AF1 | c.420G>C p.L140F | Missense Mutation (SNP) | VAF 16/402 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67577270; called by muse, mutect2
- PPFIA2 | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 8/273 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100335505; called by muse, mutect2
- PRB1 | c.809C>T p.S270F | Missense Mutation (SNP) | VAF 250/549 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.85); catalogued as rs1436944876, COSV53706037; called by muse, mutect2, varscan2
- PRC1 | c.1278G>T p.Q426H | Missense Mutation (SNP) | VAF 34/534 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as COSV62694455; called by muse, mutect2
- PRELID3B | c.349C>G p.Q117E | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54813188; called by muse, mutect2, varscan2
- PRMT5 | c.1714C>T p.H572Y | Missense Mutation (SNP) | VAF 106/277 reads (38%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.565); catalogued as rs774559209; called by muse, mutect2, varscan2
- PRORP | c.1288G>A p.V430I | Missense Mutation (SNP) | VAF 78/216 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.842); catalogued as rs139755386, COSV51622135; called by muse, mutect2
- PRUNE2 | c.5191G>C p.D1731H | Missense Mutation (SNP) | VAF 14/279 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as rs1439430383; called by muse, mutect2
- PTPDC1 | c.514G>A p.D172N (on ENST00000375360 / NM_177995.3; = p.D224N on NM_152422.4) | Missense Mutation (SNP) | VAF 98/321 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56621633; called by muse, mutect2, varscan2
- PTPN1 | c.877G>T p.E293* | Nonsense Mutation (SNP) | VAF 134/336 reads (40%) | catalogued as COSV65408977; called by muse, mutect2, varscan2
- PTPN14 | c.2410C>G p.L804V | Missense Mutation (SNP) | VAF 29/1026 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100872827, COSV65282068; called by muse, mutect2
- PTPRC | c.1253C>T p.S418L | Missense Mutation (SNP) | VAF 18/522 reads (3%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV61407517, COSV61412223; called by muse, mutect2
- PZP | c.3443G>A p.S1148N | Missense Mutation (SNP) | VAF 132/290 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.06); catalogued as rs1279642033; called by muse, mutect2, varscan2
- RAI14 | c.1535C>G p.S512* | Nonsense Mutation (SNP) | VAF 24/568 reads (4%) | catalogued as COSV99463880; called by muse, mutect2
- RAPGEF2 | c.556C>G p.P186A | Missense Mutation (SNP) | VAF 11/234 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as COSV52425957; called by muse, mutect2
- RCAN1 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 40/740 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs1351739956; called by muse, mutect2
- RCE1 | c.171G>C p.K57N | Missense Mutation (SNP) | VAF 126/322 reads (39%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.637); catalogued as COSV58992701; called by muse, mutect2, varscan2
- REV1 | c.3425C>G p.S1142C | Missense Mutation (SNP) | VAF 24/424 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs1469153179; called by muse, mutect2
- RGS12 | c.1045C>G p.H349D | Missense Mutation (SNP) | VAF 14/392 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60905780; called by muse, mutect2
- RNF17 | c.2152G>A p.D718N | Missense Mutation (SNP) | VAF 65/221 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV55038907; called by muse, mutect2, varscan2
- RTL8A | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV66188518; called by muse, mutect2
- RUSC2 | c.2279G>A p.R760K | Missense Mutation (SNP) | VAF 203/452 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV63429511; called by muse, mutect2, varscan2
- RWDD4 | c.47C>G p.S16C | Missense Mutation (SNP) | VAF 89/196 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759832355; called by muse, mutect2, varscan2
- RYR1 | c.4426G>A p.G1476R | Missense Mutation (SNP) | VAF 16/254 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62088785; called by muse, mutect2
- RYR2 | c.3244G>T p.G1082W | Missense Mutation (SNP) | VAF 95/95 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.24); catalogued as COSV63679863; called by muse, mutect2, varscan2
- SCRT2 | c.862G>C p.E288Q | Missense Mutation (SNP) | VAF 212/430 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55728766; called by muse, mutect2, varscan2
- SDCCAG8 | c.808del p.L270Ffs*15 | Frame Shift Del (DEL) | VAF 157/220 reads (71%) | catalogued as COSV59405067; called by mutect2, pindel, varscan2
- SENP5 | c.545C>T p.T182M | Missense Mutation (SNP) | VAF 212/399 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.333); catalogued as rs780858586; called by muse, mutect2, varscan2
- SERINC5 | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 20/456 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as rs935339474; called by muse, mutect2
- SF3B4 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 157/715 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54966618; called by muse, mutect2, varscan2
- SFMBT2 | c.2146G>T p.G716W | Missense Mutation (SNP) | VAF 93/216 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.514); catalogued as COSV62810538; called by muse, mutect2, varscan2
- SIN3A | c.3163G>A p.E1055K | Missense Mutation (SNP) | VAF 14/284 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64582526; called by muse, mutect2
- SIRT1 | c.2206G>A p.E736K | Missense Mutation (SNP) | VAF 30/344 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.022); catalogued as rs1564896279; called by muse, mutect2
- SLC22A11 | c.182C>T p.S61F | Missense Mutation (SNP) | VAF 225/466 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs751943384; called by muse, mutect2, varscan2
- SLC22A25 | c.1439G>A p.G480E | Missense Mutation (SNP) | VAF 17/333 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as rs1238485866, COSV60599692; called by muse, mutect2
- SLC2A10 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 34/476 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100826381; called by muse, mutect2
- SLC2A4RG | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 168/331 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV99829384; called by muse, mutect2, varscan2
- SLC49A4 | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 176/390 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1457487286; called by muse, mutect2, varscan2
- SND1 | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 113/265 reads (43%) | catalogued as COSV61241626; called by muse, mutect2, varscan2
- SOCS6 | c.115G>T p.D39Y | Missense Mutation (SNP) | VAF 132/258 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.621); catalogued as COSV101205711, COSV67546221; called by muse, mutect2, varscan2
- SPAG9 | c.3798G>C p.L1266F (on ENST00000262013 / NM_001130528.3; = p.L1252F on NM_003971.6) | Missense Mutation (SNP) | VAF 24/422 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.014); catalogued as COSV56233577, COSV56234192; called by muse, mutect2
- SPECC1L | c.3008C>T p.S1003L | Missense Mutation (SNP) | VAF 22/408 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV58660289, COSV58660732; called by muse, mutect2
- SPON1 | c.348C>T p.I116= | Splice Region (SNP) | VAF 11/197 reads (6%) | catalogued as COSV59969359; called by muse, mutect2
- SPTBN1 | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 157/503 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.746); catalogued as rs1467998194, COSV61689753; called by muse, mutect2, varscan2
- STAG1 | c.1257G>T p.L419F | Missense Mutation (SNP) | VAF 136/287 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.411); catalogued as COSV99366349; called by muse, mutect2, varscan2
- TBC1D7 | c.337C>G p.Q113E | Missense Mutation (SNP) | VAF 34/452 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.077); catalogued as COSV100568600; called by muse, mutect2
- TGS1 | c.1975G>C p.D659H | Missense Mutation (SNP) | VAF 100/223 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52703627, COSV99485395; called by muse, mutect2, varscan2
- THEM6 | c.170C>G p.S57W | Missense Mutation (SNP) | VAF 1214/1730 reads (70%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs1563820547; called by muse, mutect2
- TIAM2 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 172/366 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.178); catalogued as COSV59692856; called by muse, mutect2, varscan2
- TICRR | c.5110G>A p.E1704K | Missense Mutation (SNP) | VAF 34/492 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as rs549454379, COSV51537825; called by muse, mutect2
- TMEM223 | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 97/533 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.067); catalogued as COSV53667307, COSV99584823; called by muse, mutect2, varscan2
- TPRG1 | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 135/342 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV100800495; called by muse, mutect2, varscan2
- TRIM67 | c.1387C>G p.L463V | Missense Mutation (SNP) | VAF 26/938 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64158031, COSV64159138; called by muse, mutect2
- TSPAN5 | c.552C>G p.F184L | Missense Mutation (SNP) | VAF 68/238 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV59876782; called by muse, mutect2, varscan2
- TTN | c.89116G>C p.E29706Q (on ENST00000591111; = p.E22282Q on NM_003319.4) | Missense Mutation (SNP) | VAF 26/580 reads (4%) | PolyPhen probably damaging (0.997); catalogued as rs886055230; ClinVar: uncertain significance; called by muse, mutect2
- TTN | c.35466G>C p.E11822D (on ENST00000591111; = p.E10895D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/434 reads (3%) | PolyPhen benign (0.001); catalogued as COSV60078595; called by muse, mutect2
- TTN | c.17657G>A p.R5886K (on ENST00000591111; = p.R4959K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/379 reads (5%) | PolyPhen benign (0.005); catalogued as COSV60201781; called by muse, mutect2
- UFL1 | c.2235G>C p.K745N | Missense Mutation (SNP) | VAF 93/269 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV100990109; called by muse, mutect2, varscan2
- UGT2B4 | c.1389G>T p.W463C | Missense Mutation (SNP) | VAF 145/287 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100522349; called by muse, mutect2, varscan2
- USH2A | c.14798A>T p.Q4933L | Missense Mutation (SNP) | VAF 101/461 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.444); catalogued as rs761954201; called by muse, mutect2, varscan2
- USP34 | c.1987G>A p.E663K | Missense Mutation (SNP) | VAF 26/612 reads (4%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.011); catalogued as rs1026816059, COSV101277086; called by muse, mutect2
- USP42 | c.3032G>A p.R1011H | Missense Mutation (SNP) | VAF 27/901 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV60362873; called by muse, mutect2
- VSTM1 | c.55G>C p.D19H | Missense Mutation (SNP) | VAF 22/394 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV58074403; called by muse, mutect2
- WNK2 | c.1916C>T p.S639F | Missense Mutation (SNP) | VAF 38/568 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV52941133; called by muse, mutect2
- XIRP2 | c.3854C>T p.T1285I (on ENST00000628543; = p.T1460I on NM_152381.6) | Missense Mutation (SNP) | VAF 132/376 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV54741657; called by muse, mutect2, varscan2
- YARS2 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 44/632 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.341); catalogued as COSV61402213, COSV61402395; called by muse, mutect2
- ZC3H3 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 261/2286 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV52792418; called by muse, mutect2, varscan2
- ZNF432 | c.1824G>A p.M608I | Missense Mutation (SNP) | VAF 13/324 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV55416400; called by muse, mutect2
- ZNF496 | c.1120G>C p.E374Q | Missense Mutation (SNP) | VAF 926/1090 reads (85%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1391349068, COSV54181412; called by muse, mutect2, varscan2
- ZNF512B | c.1127C>T p.S376L | Missense Mutation (SNP) | VAF 31/599 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs139691615; called by muse, mutect2
- ZNF574 | c.2494C>T p.R832C | Missense Mutation (SNP) | VAF 204/406 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs772200753; called by muse, mutect2, varscan2
- ZNF728 | c.1336C>T p.H446Y | Missense Mutation (SNP) | VAF 152/317 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs557869573; called by muse, mutect2, varscan2
- ZNF737 | c.268A>T p.S90C | Missense Mutation (SNP) | VAF 81/139 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.325); catalogued as COSV101417733; called by muse, mutect2, varscan2
- AASS | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 12/326 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.16); called by muse, mutect2
- ABCA4 | c.5973del p.T1992Pfs*7 | Frame Shift Del (DEL) | VAF 51/281 reads (18%) | called by mutect2, pindel, varscan2
- ABCA7 | c.3402C>G p.I1134M | Missense Mutation (SNP) | VAF 14/300 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2
- ABCA9 | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 17/415 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- ABCB10 | c.122C>G p.S41W | Missense Mutation (SNP) | VAF 30/1094 reads (3%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.027); called by muse, mutect2
- AC004593.2 | c.713G>C p.R238T | Missense Mutation (SNP) | VAF 28/388 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); called by muse, mutect2
- ADAMTS20 | c.4660C>T p.Q1554* | Nonsense Mutation (SNP) | VAF 22/248 reads (9%) | called by muse, mutect2
- ADAMTSL1 | c.944G>C p.G315A | Missense Mutation (SNP) | VAF 11/202 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADAR | c.3490C>G p.L1164V | Missense Mutation (SNP) | VAF 54/612 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.412); called by muse, mutect2
- ADGB | c.173C>T p.S58L | Missense Mutation (SNP) | VAF 22/360 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2
- ADRB2 | c.463C>G p.L155V | Missense Mutation (SNP) | VAF 62/525 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- AFAP1L1 | c.1915G>C p.E639Q | Missense Mutation (SNP) | VAF 142/587 reads (24%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- AGL | c.3542G>C p.R1181T | Missense Mutation (SNP) | VAF 81/224 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGMO | c.583C>G p.L195V | Missense Mutation (SNP) | VAF 79/285 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- AICDA | c.397G>C p.G133R | Missense Mutation (SNP) | VAF 153/296 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANGPTL6 | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 265/461 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- ANKRD31 | c.2257G>T p.V753F | Missense Mutation (SNP) | VAF 362/524 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.281); called by muse, mutect2
- APC | c.1666G>C p.D556H | Missense Mutation (SNP) | VAF 95/306 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- ARF5 | c.45G>C p.K15N | Missense Mutation (SNP) | VAF 18/366 reads (5%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.066); called by muse, mutect2
- ARHGAP28 | c.817G>T p.D273Y (on ENST00000383472 / NM_001366230.1; = p.D114Y on NM_001010000.3) | Missense Mutation (SNP) | VAF 76/177 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ASXL3 | c.3287C>A p.T1096K | Missense Mutation (SNP) | VAF 149/290 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- ASXL3 | c.5081C>A p.P1694Q | Missense Mutation (SNP) | VAF 184/354 reads (52%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.003); called by muse, mutect2
- ATG2B | c.5180C>T p.S1727F | Missense Mutation (SNP) | VAF 98/283 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- ATG4B | c.376C>T p.H126Y | Missense Mutation (SNP) | VAF 18/492 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ATG9B | c.2028T>A p.D676E | Missense Mutation (SNP) | VAF 133/261 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ATM | c.5038C>A p.P1680T | Missense Mutation (SNP) | VAF 11/224 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ATP13A4 | c.2689C>G p.L897V | Missense Mutation (SNP) | VAF 13/236 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.682); called by muse, mutect2
- ATP6V1G3 | c.288G>A p.M96I | Missense Mutation (SNP) | VAF 142/366 reads (39%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, mutect2, varscan2
- AXDND1 | c.1325C>G p.S442* | Nonsense Mutation (SNP) | VAF 8/178 reads (4%) | called by muse, mutect2
- BEND5 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 18/314 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.018); called by muse, mutect2
- BMS1 | c.1111G>C p.E371Q | Missense Mutation (SNP) | VAF 113/241 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- BOP1 | c.1499G>T p.S500I | Missense Mutation (SNP) | VAF 318/4420 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.11); called by muse, mutect2
- BRINP2 | c.1335C>A p.C445* | Nonsense Mutation (SNP) | VAF 158/357 reads (44%) | called by muse, mutect2, varscan2
- BUD13 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 24/512 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.417); called by muse, mutect2
- BX255925.3 | c.76G>C p.E26Q | Missense Mutation (SNP) | VAF 203/562 reads (36%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- C19orf57 | c.1309C>G p.H437D | Missense Mutation (SNP) | VAF 114/432 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- C1GALT1C1 | c.159G>C p.L53F | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- C1orf115 | c.213C>A p.F71L | Missense Mutation (SNP) | VAF 895/1115 reads (80%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1D | c.4455C>G p.F1485L (on ENST00000350061 / NM_001128840.3; = p.F1505L on NM_000720.4) | Missense Mutation (SNP) | VAF 95/222 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CALU | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 111/252 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CAPS2 | c.1391T>G p.L464R | Missense Mutation (SNP) | VAF 55/181 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.091); called by muse, varscan2
- CCDC168 | c.7398G>T p.M2466I | Missense Mutation (SNP) | VAF 168/335 reads (50%) | SIFT tolerated (0.53); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- CCDC177 | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 24/624 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0.005); called by muse, mutect2
- CCDC196 | c.463G>C p.E155Q | Missense Mutation (SNP) | VAF 43/259 reads (17%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CCL27 | c.100T>A p.C34S | Missense Mutation (SNP) | VAF 132/287 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDC42BPA | c.4450C>G p.L1484V (on ENST00000334218 / NM_001366019.2; = p.L1471V on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/419 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDH18 | c.521T>G p.M174R | Missense Mutation (SNP) | VAF 73/282 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- CDK13 | c.3524C>T p.A1175V | Missense Mutation (SNP) | VAF 158/344 reads (46%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- CELF2 | c.1230G>C p.Q410H (on ENST00000416382 / NM_001025077.3; = p.Q423H on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 120/247 reads (49%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- CENPF | c.3802G>A p.A1268T | Missense Mutation (SNP) | VAF 112/481 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CEP250 | c.3045G>C p.L1015F | Missense Mutation (SNP) | VAF 17/283 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, mutect2
- CFAP74 | c.2184G>C p.E728D | Missense Mutation (SNP) | VAF 22/367 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0.109); called by muse, mutect2
- CLASRP | c.593A>T p.D198V | Missense Mutation (SNP) | VAF 125/280 reads (45%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- CLCN5 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 20/294 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.151); called by muse, mutect2
- CLDN1 | c.59G>T p.G20V | Missense Mutation (SNP) | VAF 61/349 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CNOT8 | c.187C>T p.Q63* | Nonsense Mutation (SNP) | VAF 20/598 reads (3%) | called by muse, mutect2
- CNTN4 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 24/274 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); called by muse, mutect2
- COL3A1 | c.1393G>T p.G465C | Missense Mutation (SNP) | VAF 212/344 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL5A2 | c.304G>A p.G102S | Missense Mutation (SNP) | VAF 62/201 reads (31%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPXM1 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 26/423 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CROCC | c.2431del p.A811Rfs*26 | Frame Shift Del (DEL) | VAF 119/486 reads (24%) | called by mutect2, pindel, varscan2
- CRYBG2 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 29/496 reads (6%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.052); called by muse, mutect2
- CRYBG3 | c.8016C>A p.F2672L | Missense Mutation (SNP) | VAF 28/192 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CSMD3 | c.4465C>G p.L1489V (on ENST00000297405 / NM_001363185.1; = p.L1385V on NM_052900.3) | Missense Mutation (SNP) | VAF 80/1083 reads (7%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.824); called by muse, mutect2
- CSN3 | c.285G>T p.Q95H | Missense Mutation (SNP) | VAF 161/344 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- CTSF | c.406G>C p.E136Q | Missense Mutation (SNP) | VAF 23/411 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2
- CTU1 | c.326G>A p.W109* | Nonsense Mutation (SNP) | VAF 34/500 reads (7%) | called by muse, mutect2
- CUTC | c.277G>C p.D93H | Missense Mutation (SNP) | VAF 20/426 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.366); called by muse, mutect2
- CWF19L2 | c.121G>C p.E41Q | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by mutect2, varscan2
- CYB5D2 | c.212G>T p.R71M | Missense Mutation (SNP) | VAF 133/134 reads (99%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- DAP | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 101/395 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DCHS1 | c.5230G>A p.E1744K | Missense Mutation (SNP) | VAF 14/414 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.067); called by muse, mutect2
- DDX23 | c.1978G>C p.E660Q | Missense Mutation (SNP) | VAF 18/318 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.017); called by muse, mutect2
- DDX55 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 109/317 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DENND4A | c.4932G>C p.W1644C | Missense Mutation (SNP) | VAF 15/394 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- DEPDC1 | c.304C>G p.Q102E | Missense Mutation (SNP) | VAF 13/229 reads (6%) | SIFT tolerated (0.9); PolyPhen benign (0.297); called by muse, mutect2
- DGKD | c.2376G>A p.R792= (on ENST00000264057 / NM_152879.3; = p.R748= on NM_003648.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 10/320 reads (3%) | called by muse, mutect2
- DHX8 | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 177/314 reads (56%) | called by muse, mutect2, varscan2
- DIP2B | c.3752C>G p.S1251C | Missense Mutation (SNP) | VAF 107/283 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DLG3 | c.158G>A p.G53D | Missense Mutation (SNP) | VAF 281/281 reads (100%) | SIFT tolerated, low confidence (0.41); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH10 | c.4130C>T p.S1377L (on ENST00000409039; = p.S1316L on NM_207437.3) | Missense Mutation (SNP) | VAF 44/455 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2
- DNAH5 | c.2453A>C p.D818A | Missense Mutation (SNP) | VAF 103/368 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNAH7 | c.979C>G p.L327V | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.109); called by muse, mutect2
- DNAH7 | c.437G>A p.G146E | Missense Mutation (SNP) | VAF 15/386 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- DNAI1 | c.557G>A p.R186K | Missense Mutation (SNP) | VAF 167/343 reads (49%) | SIFT tolerated (0.86); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DOCK2 | c.661C>T p.H221Y | Missense Mutation (SNP) | VAF 17/592 reads (3%) | SIFT tolerated (0.61); PolyPhen benign (0.292); called by muse, mutect2
- DOCK7 | c.5642A>G p.Y1881C (on ENST00000635253 / NM_001367561.1; = p.Y1850C on NM_033407.3) | Missense Mutation (SNP) | VAF 71/145 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DROSHA | c.3086A>G p.D1029G | Missense Mutation (SNP) | VAF 293/446 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- DSG4 | c.2108C>T p.S703L | Missense Mutation (SNP) | VAF 38/217 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- DTWD1 | c.167C>G p.S56* | Nonsense Mutation (SNP) | VAF 19/406 reads (5%) | called by muse, mutect2
- EEF1AKMT4-ECE2 | c.2500G>C p.E834Q | Missense Mutation (SNP) | VAF 16/422 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); called by muse, mutect2
- EGFR | c.1499-1G>A p.X500_splice | Splice Site (SNP) | VAF 134/330 reads (41%) | called by muse, mutect2, varscan2
- EIF2S2 | c.442G>C p.D148H | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- EIF3C | c.1036_1040+1del p.X346_splice | Splice Site (DEL) | VAF 44/190 reads (23%) | called by mutect2, varscan2
- EIF3L | c.573C>G p.I191M | Missense Mutation (SNP) | VAF 13/379 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- ELOA | c.1028C>G p.S343* | Nonsense Mutation (SNP) | VAF 63/367 reads (17%) | called by muse, mutect2, varscan2
- EMILIN1 | c.2764A>T p.T922S | Missense Mutation (SNP) | VAF 167/553 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- EML5 | c.352G>T p.G118* | Nonsense Mutation (SNP) | VAF 82/207 reads (40%) | called by muse, mutect2, varscan2
- ENDOU | c.517G>C p.E173Q (on ENST00000422538 / NM_001172439.2; = p.E132Q on NM_006025.4) | Missense Mutation (SNP) | VAF 84/390 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- EPC1 | c.1574G>A p.R525K | Missense Mutation (SNP) | VAF 13/384 reads (3%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.928); called by muse, mutect2
- ERCC6L | c.574C>A p.Q192K | Missense Mutation (SNP) | VAF 21/265 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2
- ERVFRD-1 | c.505C>T p.Q169* | Nonsense Mutation (SNP) | VAF 22/342 reads (6%) | called by muse, mutect2
- ERVW-1 | c.1561G>C p.E521Q | Missense Mutation (SNP) | VAF 163/319 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ESRRB | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 25/413 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.14); called by muse, mutect2
- EVX1 | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 249/493 reads (51%) | SIFT tolerated (0.49); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- EXPH5 | c.1697C>G p.S566* | Nonsense Mutation (SNP) | VAF 18/336 reads (5%) | called by muse, mutect2
- FAAP100 | c.2157G>C p.L719F | Missense Mutation (SNP) | VAF 21/738 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.099); called by muse, mutect2
- FAM13C | c.829T>C p.C277R | Missense Mutation (SNP) | VAF 137/266 reads (52%) | SIFT tolerated (0.47); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- FAM168B | c.103C>G p.P35A | Missense Mutation (SNP) | VAF 85/327 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- FAM83A | c.502G>A p.V168M | Missense Mutation (SNP) | VAF 504/722 reads (70%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- FAM86B1 | c.727G>C p.E243Q | Missense Mutation (SNP) | VAF 161/839 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- FAT4 | c.14542G>T p.E4848* | Nonsense Mutation (SNP) | VAF 139/274 reads (51%) | called by muse, mutect2, varscan2
- FBLN2 | c.1743G>T p.E581D | Missense Mutation (SNP) | VAF 117/258 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- FBN2 | c.7732C>T p.Q2578* | Nonsense Mutation (SNP) | VAF 110/377 reads (29%) | called by muse, mutect2, varscan2
- FCHSD1 | c.1895C>A p.S632Y | Missense Mutation (SNP) | VAF 40/526 reads (8%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.986); called by muse, mutect2
- FEM1A | c.263G>T p.W88L | Missense Mutation (SNP) | VAF 206/488 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FGD3 | c.1707C>G p.F569L | Missense Mutation (SNP) | VAF 13/310 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); called by muse, mutect2
- FGD5 | c.903G>C p.K301N | Missense Mutation (SNP) | VAF 22/459 reads (5%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.006); called by muse, mutect2
- FKTN | c.1321C>T p.P441S | Missense Mutation (SNP) | VAF 32/451 reads (7%) | SIFT tolerated (0.69); PolyPhen benign (0.045); called by muse, mutect2
- FLG2 | c.7123C>T p.H2375Y | Missense Mutation (SNP) | VAF 17/310 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.104); called by muse, mutect2
- FNBP1 | c.1587G>C p.E529D | Missense Mutation (SNP) | VAF 36/424 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.042); called by muse, mutect2
- FOXB1 | c.133G>C p.D45H | Missense Mutation (SNP) | VAF 18/391 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- FRMD1 | c.64C>G p.P22A | Missense Mutation (SNP) | VAF 33/471 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.026); called by muse, mutect2
- FSCN3 | c.102G>C p.K34N | Missense Mutation (SNP) | VAF 148/293 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- FYCO1 | c.3877G>C p.E1293Q | Missense Mutation (SNP) | VAF 30/418 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); called by muse, mutect2
- GABRG2 | c.927C>G p.S309R (on ENST00000361925 / NM_001375343.1; = p.S269R on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 243/379 reads (64%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GAD1 | c.476C>T p.S159F | Missense Mutation (SNP) | VAF 119/455 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- GALNT8 | c.671C>G p.S224* | Nonsense Mutation (SNP) | VAF 14/184 reads (8%) | called by muse, mutect2
- GBP2 | c.183G>C p.K61N | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- GDA | c.166A>G p.K56E | Missense Mutation (SNP) | VAF 81/158 reads (51%) | SIFT tolerated (0.3); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GEN1 | c.397G>C p.G133R | Missense Mutation (SNP) | VAF 85/328 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GHITM | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 81/175 reads (46%) | SIFT tolerated (0.9); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- GIP | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 81/301 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- GIPC3 | c.1052C>G p.S351C | Missense Mutation (SNP) | VAF 188/397 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- GIPC3 | c.1916C>G p.S639C | Missense Mutation (SNP) | VAF 167/400 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- GNB1 | c.107A>G p.N36S | Missense Mutation (SNP) | VAF 22/375 reads (6%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2
- GOLGB1 | c.7949C>T p.S2650F | Missense Mutation (SNP) | VAF 20/262 reads (8%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.61); called by muse, mutect2
- GPRASP1 | c.2926G>A p.E976K | Missense Mutation (SNP) | VAF 24/185 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRID1 | c.2466C>G p.D822E | Missense Mutation (SNP) | VAF 204/417 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- GRIK5 | c.1316G>T p.G439V | Missense Mutation (SNP) | VAF 161/365 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRIN2D | c.1686C>A p.S562R | Missense Mutation (SNP) | VAF 201/427 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRIP2 | c.2632del p.D878Tfs*41 (on ENST00000619221; = p.D781Tfs*41 on NM_001080423.4) | Frame Shift Del (DEL) | VAF 183/476 reads (38%) | called by mutect2, pindel, varscan2
- GRK4 | c.1141C>G p.Q381E (on ENST00000398052 / NM_182982.3; = p.Q349E on NM_005307.3) | Missense Mutation (SNP) | VAF 72/299 reads (24%) | SIFT tolerated (0.98); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- GRM6 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 36/710 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.028); called by muse, mutect2
- GSR | c.1568G>T p.*523Lext*13 | Nonstop Mutation (SNP) | VAF 99/315 reads (31%) | called by muse, mutect2, varscan2
- GTF2A1 | c.169G>C p.D57H | Missense Mutation (SNP) | VAF 14/356 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2
- HABP4 | c.1149G>T p.R383S | Missense Mutation (SNP) | VAF 156/284 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- HERC6 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HIF1A | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 24/355 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- HIPK3 | c.1397del p.Y466Sfs*9 | Frame Shift Del (DEL) | VAF 105/234 reads (45%) | called by mutect2, pindel, varscan2
- HMBOX1 | c.959G>C p.R320T | Missense Mutation (SNP) | VAF 72/262 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- HNF1A | c.1658C>A p.S553Y | Missense Mutation (SNP) | VAF 324/663 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- HSF1 | c.337G>C p.E113Q | Missense Mutation (SNP) | VAF 127/1852 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2
- HSP90AA1 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 147/340 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HUS1B | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 37/578 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- IGFN1 | c.3395G>T p.W1132L (on ENST00000295591 / NM_001367841.1; = p.W3589L on NM_001164586.2) | Missense Mutation (SNP) | VAF 150/785 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- IL24 | c.620G>C p.*207Sext*52 | Nonstop Mutation (SNP) | VAF 76/594 reads (13%) | called by muse, mutect2, varscan2
- IMMP1L | c.298G>T p.D100Y | Missense Mutation (SNP) | VAF 78/167 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- INPP5J | c.1894G>T p.D632Y (on ENST00000331075 / NM_001284285.2; = p.D264Y on NM_001002837.2) | Missense Mutation (SNP) | VAF 175/293 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- INTS9 | c.1729G>C p.D577H | Missense Mutation (SNP) | VAF 142/511 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITGBL1 | c.628G>T p.G210C | Missense Mutation (SNP) | VAF 153/297 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITPR1 | c.604G>C p.D202H | Missense Mutation (SNP) | VAF 73/206 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- ITPR2 | c.812C>G p.S271* | Nonsense Mutation (SNP) | VAF 97/234 reads (41%) | called by muse, mutect2, varscan2
- JTB | c.279C>G p.F93L | Missense Mutation (SNP) | VAF 19/558 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2
- JUN | c.313G>C p.D105H | Missense Mutation (SNP) | VAF 19/460 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- KAT14 | c.1422G>T p.R474S | Missense Mutation (SNP) | VAF 148/324 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- KATNIP | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 18/300 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2
- KBTBD7 | c.355G>C p.A119P | Missense Mutation (SNP) | VAF 211/410 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- KCNK9 | c.323C>A p.A108D | Missense Mutation (SNP) | VAF 122/820 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- KDM1A | c.571C>G p.Q191E | Missense Mutation (SNP) | VAF 22/366 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.049); called by muse, mutect2
- KDM3A | c.2585C>G p.S862C | Missense Mutation (SNP) | VAF 36/669 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.264); called by muse, mutect2
- KIF16B | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 21/352 reads (6%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); called by muse, mutect2
- KIF3A | c.1588G>C p.E530Q | Missense Mutation (SNP) | VAF 65/291 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- KPRP | c.1360C>T p.Q454* | Nonsense Mutation (SNP) | VAF 18/442 reads (4%) | called by muse, mutect2
- KRIT1 | c.144G>C p.K48N | Missense Mutation (SNP) | VAF 45/245 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- LHX3 | c.841C>A p.Q281K (on ENST00000371748 / NM_178138.6; = p.Q286K on NM_014564.5) | Missense Mutation (SNP) | VAF 251/508 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LIG1 | c.628G>T p.E210* | Nonsense Mutation (SNP) | VAF 29/389 reads (7%) | called by muse, mutect2
- LIMK1 | c.929C>G p.S310C | Missense Mutation (SNP) | VAF 26/552 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); called by muse, mutect2
- LIX1 | c.512A>G p.H171R | Missense Mutation (SNP) | VAF 88/334 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- LMOD3 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 192/418 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0.024); called by muse, varscan2
- LMOD3 | c.395G>C p.R132T | Missense Mutation (SNP) | VAF 116/288 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.012); called by muse, varscan2
- LRRC66 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 9/221 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.082); called by muse, mutect2
- LSR | c.389C>G p.S130C | Missense Mutation (SNP) | VAF 30/454 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LYPD5 | c.208G>T p.V70L (on ENST00000377950 / NM_001031749.3; = p.V27L on NM_182573.2) | Missense Mutation (SNP) | VAF 202/413 reads (49%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2
- LZTFL1 | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 163/355 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MAGEL2 | c.362A>G p.Q121R | Missense Mutation (SNP) | VAF 242/469 reads (52%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2, varscan2
- MAN1B1 | c.300C>G p.F100L | Missense Mutation (SNP) | VAF 110/323 reads (34%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP3K15 | c.1810C>G p.Q604E | Missense Mutation (SNP) | VAF 8/135 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.021); called by muse, mutect2
- MB | c.115G>C p.E39Q | Missense Mutation (SNP) | VAF 57/219 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MBTD1 | c.1171G>T p.E391* | Nonsense Mutation (SNP) | VAF 13/288 reads (5%) | called by muse, mutect2
- MED13L | c.2557C>T p.P853S | Missense Mutation (SNP) | VAF 19/312 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.121); called by muse, mutect2
- MGA | c.357G>C p.L119F | Missense Mutation (SNP) | VAF 94/245 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- MIB2 | c.2302C>T p.L768F | Missense Mutation (SNP) | VAF 15/317 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MROH2A | c.2472C>G p.F824L | Missense Mutation (SNP) | VAF 80/261 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- MT2A | c.154G>A p.G52R | Missense Mutation (SNP) | VAF 21/346 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.58); called by muse, mutect2
- MTHFD1 | c.1570G>A p.D524N | Missense Mutation (SNP) | VAF 35/209 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- MTTP | c.2624C>G p.S875* | Nonsense Mutation (SNP) | VAF 54/317 reads (17%) | called by muse, mutect2, varscan2
- MXD3 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 176/535 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- N4BP1 | c.1478C>T p.S493L | Missense Mutation (SNP) | VAF 18/451 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2
- NAMPT | c.847A>G p.I283V | Missense Mutation (SNP) | VAF 122/274 reads (45%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.978); called by muse, mutect2
- NAP1L3 | c.586C>G p.P196A | Missense Mutation (SNP) | VAF 23/224 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- NAV3 | c.5609C>T p.S1870L (on ENST00000397909 / NM_001024383.2; = p.S1848L on NM_014903.6) | Missense Mutation (SNP) | VAF 27/441 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.05); called by muse, mutect2
- NBEA | c.6046G>T p.E2016* | Nonsense Mutation (SNP) | VAF 123/266 reads (46%) | called by muse, mutect2, varscan2
- NBEAL2 | c.2803C>G p.L935V | Missense Mutation (SNP) | VAF 51/262 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- NCAPG2 | c.2395C>G p.L799V | Missense Mutation (SNP) | VAF 99/211 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- NENF | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 26/440 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- NEURL1 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 23/254 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.038); called by muse, mutect2
- NFASC | c.239G>C p.R80T (on ENST00000339876 / NM_001378329.1; = p.R74T on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 85/337 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NFAT5 | c.2386G>A p.D796N | Missense Mutation (SNP) | VAF 123/303 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NKD2 | c.893G>T p.R298M | Missense Mutation (SNP) | VAF 561/846 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NNMT | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 103/280 reads (37%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- NOL11 | c.883C>G p.Q295E | Missense Mutation (SNP) | VAF 152/377 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- NOS2 | c.1480G>C p.E494Q | Missense Mutation (SNP) | VAF 16/354 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); called by muse, mutect2
- NPY1R | c.624G>T p.R208S | Missense Mutation (SNP) | VAF 119/266 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- NR2E1 | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 38/638 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.06); called by muse, mutect2
- NRXN1 | c.526G>C p.E176Q | Missense Mutation (SNP) | VAF 22/634 reads (3%) | SIFT tolerated (0.46); PolyPhen benign (0.374); called by muse, mutect2
- NSMAF | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 12/238 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.031); called by muse, mutect2
- NUP210L | c.3124G>A p.D1042N | Missense Mutation (SNP) | VAF 114/538 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2
- NUTM2D | c.1222del p.R408Gfs*68 | Frame Shift Del (DEL) | VAF 96/785 reads (12%) | called by pindel, varscan2
- OBSCN | c.20046G>C p.W6682C | Missense Mutation (SNP) | VAF 38/1148 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- OR11L1 | c.8C>A p.P3H | Missense Mutation (SNP) | VAF 54/362 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- OR2AG2 | c.950A>T p.*317Lext*? | Nonstop Mutation (SNP) | VAF 108/228 reads (47%) | called by muse, mutect2
- OR2AJ1 | c.776A>G p.Y259C | Missense Mutation (SNP) | VAF 130/796 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2H1 | c.559T>A p.C187S | Missense Mutation (SNP) | VAF 223/466 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- OR2M5 | c.245C>A p.A82D | Missense Mutation (SNP) | VAF 791/972 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- OR4P4 | c.833C>A p.P278H | Missense Mutation (SNP) | VAF 178/368 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR6B2 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 105/520 reads (20%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- OR6N2 | c.808C>T p.L270F | Missense Mutation (SNP) | VAF 373/498 reads (75%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.538); called by muse, mutect2, varscan2
- OR7D4 | c.778C>G p.L260V | Missense Mutation (SNP) | VAF 95/323 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- OVCH1 | c.1344G>T p.W448C | Missense Mutation (SNP) | VAF 85/188 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- PARD3 | c.2077C>A p.P693T | Missense Mutation (SNP) | VAF 99/181 reads (55%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- PARD3B | c.3517C>G p.Q1173E (on ENST00000406610 / NM_001302769.2; = p.Q1104E on NM_057177.7) | Missense Mutation (SNP) | VAF 37/685 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2
- PATZ1 | c.1948C>T p.Q650* | Nonsense Mutation (SNP) | VAF 350/567 reads (62%) | called by muse, mutect2, varscan2
- PAX8 | c.1166C>G p.S389C | Missense Mutation (SNP) | VAF 19/579 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2
- PCDH17 | c.2024C>A p.A675E | Missense Mutation (SNP) | VAF 164/344 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- PCLO | c.6344C>T p.S2115F | Missense Mutation (SNP) | VAF 20/329 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2
- PDE9A | c.398G>A p.R133K | Missense Mutation (SNP) | VAF 28/558 reads (5%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0.01); called by muse, mutect2
- PDF | c.517G>C p.E173Q | Missense Mutation (SNP) | VAF 161/406 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- PHACTR2 | c.1617G>C p.K539N | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- PHKG2 | c.377C>G p.S126C | Missense Mutation (SNP) | VAF 25/376 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); called by muse, mutect2
- PIK3C2A | c.3394G>C p.E1132Q | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); called by muse, mutect2
- PINK1 | c.850T>C p.S284P | Missense Mutation (SNP) | VAF 237/471 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PLCB3 | c.1684G>A p.E562K | Missense Mutation (SNP) | VAF 40/280 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- PLOD1 | c.1003G>C p.E335Q | Missense Mutation (SNP) | VAF 18/286 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2
- PLPPR3 | c.369C>G p.F123L | Missense Mutation (SNP) | VAF 34/579 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- PLPPR4 | c.1951G>C p.A651P | Missense Mutation (SNP) | VAF 109/216 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PNMA6F | c.1726C>A p.P576T | Missense Mutation (SNP) | VAF 90/91 reads (99%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- PNMT | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 16/457 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.409); called by muse, mutect2
- POGZ | c.2664A>T p.K888N | Missense Mutation (SNP) | VAF 427/613 reads (70%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PPP1R13L | c.2347G>A p.E783K | Missense Mutation (SNP) | VAF 28/706 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.124); called by muse, mutect2
- PPTC7 | c.784G>T p.E262* | Nonsense Mutation (SNP) | VAF 25/344 reads (7%) | called by muse, mutect2
- PRAME | c.1468T>C p.C490R | Missense Mutation (SNP) | VAF 320/579 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- PRAMEF10 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 49/234 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- PRKD1 | c.2057T>C p.L686S | Missense Mutation (SNP) | VAF 95/197 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PRLR | c.484G>C p.G162R | Missense Mutation (SNP) | VAF 112/425 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PROSER1 | c.880C>T p.H294Y | Missense Mutation (SNP) | VAF 65/345 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PRPF3 | c.77C>G p.S26* | Nonsense Mutation (SNP) | VAF 30/465 reads (6%) | called by muse, mutect2
- PRPF40A | c.444G>C p.M148I | Missense Mutation (SNP) | VAF 15/390 reads (4%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.584); called by muse, mutect2
- PRR14L | c.2725G>A p.D909N | Missense Mutation (SNP) | VAF 182/365 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PRRG3 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 272/332 reads (82%) | SIFT tolerated (0.25); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- PRTFDC1 | c.19G>C p.E7Q | Missense Mutation (SNP) | VAF 16/449 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- PTPDC1 | c.1610C>G p.S537C (on ENST00000375360 / NM_177995.3; = p.S589C on NM_152422.4) | Missense Mutation (SNP) | VAF 206/389 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAB19 | c.257A>C p.Y86S | Missense Mutation (SNP) | VAF 16/530 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RAB36 | c.837C>G p.F279L | Missense Mutation (SNP) | VAF 28/422 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.31); called by muse, mutect2
- RAB5A | c.76C>G p.L26V | Missense Mutation (SNP) | VAF 137/311 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- RAD54L | c.1780G>C p.D594H | Missense Mutation (SNP) | VAF 30/418 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RDH12 | c.19C>A p.L7M | Missense Mutation (SNP) | VAF 144/295 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- RGL4 | c.1140G>A p.M380I | Missense Mutation (SNP) | VAF 118/382 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.124); called by muse, mutect2
- RGS2 | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 15/302 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); called by muse, mutect2
- ROM1 | c.660C>A p.H220Q | Missense Mutation (SNP) | VAF 24/400 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.223); called by muse, mutect2
- RP1 | c.2251G>C p.E751Q | Missense Mutation (SNP) | VAF 124/309 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- RPN1 | c.631C>T p.Q211* | Nonsense Mutation (SNP) | VAF 12/249 reads (5%) | called by muse, mutect2
- RRN3 | c.1197C>G p.I399M | Missense Mutation (SNP) | VAF 43/205 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- RUSC2 | c.2804C>T p.S935F | Missense Mutation (SNP) | VAF 22/362 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); called by muse, mutect2
- RXFP4 | c.851A>T p.Y284F | Missense Mutation (SNP) | VAF 161/637 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- SAMM50 | c.186C>G p.I62M | Missense Mutation (SNP) | VAF 16/381 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.219); called by muse, mutect2
- SAV1 | c.275G>A p.R92K | Missense Mutation (SNP) | VAF 19/316 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.444); called by muse, mutect2
- SCAF1 | c.1835C>T p.S612F | Missense Mutation (SNP) | VAF 137/282 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- SCART1 | c.1731G>T p.W577C | Missense Mutation (SNP) | VAF 307/596 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- SECISBP2L | c.1822G>C p.D608H (on ENST00000559471 / NM_001193489.2; = p.D563H on NM_014701.4) | Missense Mutation (SNP) | VAF 144/305 reads (47%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEMA5A | c.2063G>C p.G688A | Missense Mutation (SNP) | VAF 235/361 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- SFPQ | c.824C>T p.S275L | Missense Mutation (SNP) | VAF 13/250 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2
- SH3D19 | c.1154C>G p.S385* | Nonsense Mutation (SNP) | VAF 29/320 reads (9%) | called by muse, mutect2
- SHC1 | c.1703C>G p.S568C (on ENST00000368445 / NM_183001.5; = p.S459C on NM_003029.5) | Missense Mutation (SNP) | VAF 27/749 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SIRPA | c.843G>T p.Q281H | Missense Mutation (SNP) | VAF 114/251 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- SLC12A2 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 28/622 reads (5%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.472); called by muse, mutect2
- SLC12A5 | c.156C>G p.I52M (on ENST00000454036 / NM_001134771.2; = p.I29M on NM_020708.5) | Missense Mutation (SNP) | VAF 87/266 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- SLC12A7 | c.406A>G p.I136V | Missense Mutation (SNP) | VAF 21/848 reads (2%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); called by muse, mutect2
- SLC13A4 | c.1230C>G p.Y410* | Nonsense Mutation (SNP) | VAF 71/154 reads (46%) | called by muse, mutect2, varscan2
- SLC30A6 | c.532G>C p.D178H | Missense Mutation (SNP) | VAF 90/321 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- SLC30A6 | c.554G>A p.G185E | Missense Mutation (SNP) | VAF 76/340 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- SLC39A10 | c.98C>A p.P33H | Missense Mutation (SNP) | VAF 145/439 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- SLC39A7 | c.361G>C p.G121R | Missense Mutation (SNP) | VAF 193/516 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC8A1 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 14/498 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLCO2B1 | c.446C>A p.P149H | Missense Mutation (SNP) | VAF 125/241 reads (52%) | SIFT tolerated (0.53); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SLK | c.2159G>A p.G720E | Missense Mutation (SNP) | VAF 10/231 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2
- SMARCA2 | c.1315G>C p.E439Q | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- SMARCE1 | c.1093G>C p.E365Q | Missense Mutation (SNP) | VAF 24/488 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.097); called by muse, mutect2
- SMYD1 | c.44A>T p.E15V | Missense Mutation (SNP) | VAF 145/459 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- SNRNP200 | c.55C>G p.L19V | Missense Mutation (SNP) | VAF 14/364 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); called by muse, mutect2
- SP140 | c.578C>G p.S193C | Missense Mutation (SNP) | VAF 14/276 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.195); called by muse, mutect2
- SPOCD1 | c.2139G>C p.E713D | Missense Mutation (SNP) | VAF 132/312 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- SRCAP | c.8855G>T p.G2952V | Missense Mutation (SNP) | VAF 256/499 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- SRCAP | c.9538G>T p.E3180* | Nonsense Mutation (SNP) | VAF 19/473 reads (4%) | called by muse, mutect2
- STK17A | c.59C>G p.S20W | Missense Mutation (SNP) | VAF 184/395 reads (47%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- STRA8 | c.629T>A p.L210Q (on ENST00000275764; = p.L188Q on NM_182489.2) | Missense Mutation (SNP) | VAF 272/527 reads (52%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- SYT10 | c.549G>T p.Q183H | Missense Mutation (SNP) | VAF 125/289 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TAF7 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 13/384 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.156); called by muse, mutect2
- TANC2 | c.2471G>T p.G824V | Missense Mutation (SNP) | VAF 105/346 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TANC2 | c.3998G>T p.R1333M | Missense Mutation (SNP) | VAF 81/369 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TBC1D17 | c.1062G>C p.W354C | Missense Mutation (SNP) | VAF 22/437 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TBC1D22A | c.484C>G p.L162V | Missense Mutation (SNP) | VAF 17/433 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.015); called by muse, mutect2
- TCERG1L | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 42/518 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.013); called by muse, mutect2
- TESK2 | c.1522C>G p.Q508E | Missense Mutation (SNP) | VAF 16/352 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2
- TEX37 | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 46/371 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- TJP3 | c.2359C>T p.H787Y | Missense Mutation (SNP) | VAF 154/300 reads (51%) | SIFT tolerated (0.44); PolyPhen benign (0.178); called by muse, varscan2
- TLR4 | c.2263C>T p.Q755* (on ENST00000355622 / NM_138554.5; = p.Q715* on NM_003266.4) | Nonsense Mutation (SNP) | VAF 60/323 reads (19%) | called by muse, mutect2, varscan2
- TMEM134 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 209/516 reads (41%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- TMEM215 | c.92G>T p.G31V | Missense Mutation (SNP) | VAF 188/352 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- TNC | c.4487C>T p.S1496L | Missense Mutation (SNP) | VAF 185/351 reads (53%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- TPP1 | c.1594G>C p.E532Q | Missense Mutation (SNP) | VAF 30/411 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TPP2 | c.892G>A p.D298N | Missense Mutation (SNP) | VAF 108/271 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- TRAPPC10 | c.2236C>T p.Q746* | Nonsense Mutation (SNP) | VAF 15/283 reads (5%) | called by muse, mutect2
- TRAV13-2 | c.137C>T p.S46L | Missense Mutation (SNP) | VAF 110/270 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- TRIM33 | c.2539G>A p.E847K | Missense Mutation (SNP) | VAF 104/286 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- TRIM47 | c.248C>T p.S83L | Missense Mutation (SNP) | VAF 228/749 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRPC6 | c.931G>T p.E311* | Nonsense Mutation (SNP) | VAF 91/188 reads (48%) | called by muse, mutect2, varscan2
- TRPM7 | c.5309G>T p.G1770V | Missense Mutation (SNP) | VAF 78/172 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRPS1 | c.3325G>C p.D1109H (on ENST00000220888 / NM_001330599.2; = p.D1122H on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 113/1135 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TSEN34 | c.229C>T p.R77W | Missense Mutation (SNP) | VAF 134/302 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- TSPYL6 | c.352G>T p.E118* | Nonsense Mutation (SNP) | VAF 20/724 reads (3%) | called by muse, mutect2
- TUBGCP3 | c.2146C>G p.H716D | Missense Mutation (SNP) | VAF 95/236 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- TXLNB | c.1429G>C p.E477Q | Missense Mutation (SNP) | VAF 124/315 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- UBE2J2 | c.661C>G p.Q221E | Missense Mutation (SNP) | VAF 262/558 reads (47%) | SIFT tolerated (0.63); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- UFSP2 | c.218G>A p.G73E | Missense Mutation (SNP) | VAF 18/298 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2
- UNC80 | c.7347C>G p.N2449K | Missense Mutation (SNP) | VAF 97/322 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.015); called by muse, varscan2
- UPF3B | c.1435G>C p.E479Q (on ENST00000276201 / NM_080632.3; = p.E466Q on NM_023010.3) | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- USH2A | c.463A>C p.K155Q | Missense Mutation (SNP) | VAF 93/403 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- USP15 | c.1642G>A p.D548N (on ENST00000280377 / NM_001351159.2; = p.D519N on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/139 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- UTP18 | c.1435C>G p.L479V | Missense Mutation (SNP) | VAF 25/243 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- UTP25 | c.1284A>T p.G428= | Splice Region (SNP) | VAF 98/288 reads (34%) | called by muse, mutect2, varscan2
- VPS13B | c.10561G>A p.E3521K | Missense Mutation (SNP) | VAF 116/652 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- VPS13C | c.4540G>C p.D1514H (on ENST00000644861 / NM_020821.3; = p.D1471H on NM_017684.5) | Missense Mutation (SNP) | VAF 19/202 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- VPS8 | c.1215C>G p.I405M (on ENST00000625842 / NM_001349294.1; = p.I403M on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/286 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); called by muse, mutect2
- VWDE | c.1979C>G p.S660C | Missense Mutation (SNP) | VAF 18/357 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2
- WAPL | c.1147G>C p.E383Q | Missense Mutation (SNP) | VAF 28/338 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- WWC2 | c.684C>G p.I228M | Missense Mutation (SNP) | VAF 9/180 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- YES1 | c.1094G>A p.G365E | Missense Mutation (SNP) | VAF 121/279 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- YIPF1 | c.824G>A p.G275D | Missense Mutation (SNP) | VAF 70/153 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZBTB14 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 13/414 reads (3%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); called by muse, mutect2
- ZC3H11B | c.1103G>T p.R368I | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by mutect2, varscan2
- ZNF227 | c.2242G>C p.E748Q | Missense Mutation (SNP) | VAF 16/390 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0.23); called by muse, mutect2
- ZNF251 | c.261G>C p.L87F | Missense Mutation (SNP) | VAF 127/901 reads (14%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ZNF462 | c.1930G>A p.E644K | Missense Mutation (SNP) | VAF 99/355 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- ZNF530 | c.1429G>A p.D477N | Missense Mutation (SNP) | VAF 20/462 reads (4%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2
- ZNF540 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 104/216 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF606 | c.1684C>T p.H562Y | Missense Mutation (SNP) | VAF 156/360 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF658 | c.2467G>T p.E823* | Nonsense Mutation (SNP) | VAF 143/294 reads (49%) | called by muse, mutect2, varscan2
- ZNF8 | c.232G>C p.E78Q | Missense Mutation (SNP) | VAF 17/332 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); called by muse, mutect2
- ZNF84 | c.1189C>G p.H397D | Missense Mutation (SNP) | VAF 83/263 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- ZSWIM4 | c.1735C>G p.P579A | Missense Mutation (SNP) | VAF 32/382 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.561); called by muse, mutect2
- ABCA8 | c.4170G>A p.L1390= | Silent (SNP) | VAF 113/397 reads (28%) | called by muse, mutect2, varscan2
- ABCB9 | c.1203G>T p.L401= | Silent (SNP) | VAF 22/418 reads (5%) | called by muse, mutect2
- ABCC10 | c.1188G>A p.G396= (on ENST00000372530 / NM_001198934.2; = p.G353= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/406 reads (5%) | called by muse, mutect2
- ACSM2A | c.69C>T p.L23= | Silent (SNP) | VAF 88/238 reads (37%) | catalogued as rs774339388; called by muse, mutect2, varscan2
- ACTL6B | c.897C>T p.L299= | Silent (SNP) | VAF 110/247 reads (45%) | called by muse, mutect2, varscan2
- AP1B1 | c.780G>C p.V260= | Silent (SNP) | VAF 250/416 reads (60%) | called by muse, mutect2, varscan2
- ARHGAP15 | c.426A>G p.A142= | Silent (SNP) | VAF 299/455 reads (66%) | called by muse, mutect2, varscan2
- ARHGAP6 | c.630G>C p.R210= | Silent (SNP) | VAF 159/159 reads (100%) | called by muse, mutect2, varscan2
- ARHGEF2 | c.1419C>G p.L473= (on ENST00000361247 / NM_001162383.2; = p.L445= on NM_004723.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 35/730 reads (5%) | called by muse, mutect2
- ARHGEF2 | c.1191C>T p.L397= (on ENST00000361247 / NM_001162383.2; = p.L369= on NM_004723.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 17/634 reads (3%) | catalogued as rs1406695889; called by muse, mutect2
- ARID1A | c.6465C>T p.L2155= | Silent (SNP) | VAF 38/565 reads (7%) | catalogued as rs550842970; called by muse, mutect2
- ARSF | c.39G>A p.V13= | Silent (SNP) | VAF 138/138 reads (100%) | called by muse, mutect2, varscan2
- ATE1 | c.429C>T p.L143= | Silent (SNP) | VAF 105/260 reads (40%) | catalogued as COSV56437779; called by muse, mutect2, varscan2
- ATL2 | c.339C>T p.F113= | Silent (SNP) | VAF 70/267 reads (26%) | called by muse, mutect2, varscan2
- ATP2A2 | c.2934C>T p.L978= | Silent (SNP) | VAF 53/334 reads (16%) | catalogued as rs767331508, COSV57875674; called by muse, mutect2, varscan2
- ATXN7 | c.1656G>A p.E552= | Silent (SNP) | VAF 26/341 reads (8%) | catalogued as rs1036346499; called by muse, mutect2
- BBS9 | c.540G>T p.L180= | Silent (SNP) | VAF 281/453 reads (62%) | called by muse, mutect2, varscan2
- BCAS3 | c.2202C>T p.P734= (on ENST00000390652 / NM_001353144.2; = p.P719= on NM_017679.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 128/403 reads (32%) | catalogued as rs758111943; called by muse, mutect2, varscan2
- BFAR | c.27G>A p.V9= | Silent (SNP) | VAF 151/325 reads (46%) | catalogued as rs779360966; called by muse, mutect2, varscan2
- BICC1 | c.2199G>A p.Q733= | Silent (SNP) | VAF 95/243 reads (39%) | called by muse, mutect2, varscan2
- BTBD11 | c.1647C>T p.A549= (on ENST00000280758 / NM_001018072.2; = p.A86= on NM_001017523.2) | Silent (SNP) | VAF 85/172 reads (49%) | catalogued as rs777195666; called by muse, mutect2, varscan2
- C14orf28 | c.186C>T p.F62= | Silent (SNP) | VAF 16/269 reads (6%) | catalogued as rs907864080, COSV57332835, COSV57334153; called by muse, mutect2
- CACNB2 | c.1369C>T p.L457= (on ENST00000324631 / NM_201596.3; = p.L402= on NM_000724.4) | Silent (SNP) | VAF 34/440 reads (8%) | catalogued as COSV56653852, COSV99030389; called by muse, mutect2
- CALHM3 | c.21C>G p.L7= | Silent (SNP) | VAF 17/260 reads (7%) | called by muse, mutect2
- CAPN15 | c.2820C>T p.V940= | Silent (SNP) | VAF 18/616 reads (3%) | catalogued as COSV54838899; called by muse, mutect2
- CCDC178 | c.438C>G p.V146= | Silent (SNP) | VAF 15/278 reads (5%) | called by muse, mutect2
- CCNF | c.657G>A p.L219= | Silent (SNP) | VAF 22/362 reads (6%) | catalogued as COSV99563971; called by muse, mutect2
- CD1E | c.231G>A p.L77= | Silent (SNP) | VAF 321/638 reads (50%) | catalogued as COSV63773282; called by muse, mutect2, varscan2
- CDH8 | c.1098C>T p.F366= | Silent (SNP) | VAF 173/309 reads (56%) | called by muse, mutect2, varscan2
- CEACAM19 | c.591G>A p.R197= | Silent (SNP) | VAF 141/322 reads (44%) | catalogued as rs1372414914; called by muse, mutect2, varscan2
- CEP85 | c.711G>T p.R237= | Silent (SNP) | VAF 220/422 reads (52%) | catalogued as rs748406698; called by muse, mutect2, varscan2
- CFAP73 | c.621C>T p.L207= | Silent (SNP) | VAF 26/480 reads (5%) | called by muse, mutect2
- CHRM3 | c.261C>A p.I87= | Silent (SNP) | VAF 157/157 reads (100%) | catalogued as rs754466236; called by muse, mutect2, varscan2
- CHST2 | c.1215G>T p.T405= | Silent (SNP) | VAF 149/298 reads (50%) | catalogued as COSV58887013; called by muse, mutect2, varscan2
- CMYA5 | c.4614G>A p.K1538= | Silent (SNP) | VAF 168/491 reads (34%) | catalogued as rs1561208871; called by muse, mutect2, varscan2
- COL4A5 | c.732C>A p.I244= | Silent (SNP) | VAF 24/184 reads (13%) | called by muse, mutect2, varscan2
- COL6A6 | c.945C>T p.L315= | Silent (SNP) | VAF 31/317 reads (10%) | called by muse, mutect2
- COL7A1 | c.5520G>A p.L1840= | Silent (SNP) | VAF 29/346 reads (8%) | catalogued as rs1001076813; called by muse, mutect2
- COLGALT1 | c.222C>G p.L74= | Silent (SNP) | VAF 161/373 reads (43%) | catalogued as rs1427261741; called by muse, mutect2, varscan2
- CUL3 | c.321A>G p.Q107= | Silent (SNP) | VAF 80/307 reads (26%) | called by muse, mutect2, varscan2
- CUX1 | c.2280C>T p.L760= | Silent (SNP) | VAF 25/564 reads (4%) | catalogued as rs782045469, COSV99472226; called by muse, mutect2
- CYB561A3 | c.279C>T p.L93= | Silent (SNP) | VAF 202/427 reads (47%) | called by muse, mutect2, varscan2
- DAXX | c.327C>G p.L109= | Silent (SNP) | VAF 38/648 reads (6%) | catalogued as COSV99801976; called by muse, mutect2
- DCHS1 | c.1914G>C p.V638= | Silent (SNP) | VAF 157/309 reads (51%) | called by muse, mutect2, varscan2
- DDX19A | c.1143C>G p.G381= | Silent (SNP) | VAF 192/357 reads (54%) | called by muse, mutect2, varscan2
- DDX19B | c.627C>T p.I209= | Silent (SNP) | VAF 14/295 reads (5%) | catalogued as rs1433752799, COSV55363991; called by muse, mutect2
- DHTKD1 | c.2451G>A p.V817= | Silent (SNP) | VAF 20/423 reads (5%) | called by muse, mutect2
- DLGAP3 | c.1278C>T p.T426= | Silent (SNP) | VAF 147/281 reads (52%) | called by muse, mutect2, varscan2
- DNAH12 | c.5790G>A p.Q1930= (on ENST00000351747; = p.Q1949= on NM_001366028.2) | Silent (SNP) | VAF 91/198 reads (46%) | catalogued as rs1352921219; called by muse, mutect2, varscan2
- DNMT3B | c.1773C>G p.L591= | Silent (SNP) | VAF 89/212 reads (42%) | called by muse, mutect2, varscan2
- DNMT3B | c.2271G>A p.Q757= | Silent (SNP) | VAF 101/250 reads (40%) | called by muse, mutect2, varscan2
- DRD2 | c.165G>T p.V55= | Silent (SNP) | VAF 203/471 reads (43%) | called by muse, mutect2, varscan2
- EDNRB | c.336G>A p.S112= (on ENST00000377211 / NM_001201397.1; = p.S22= on NM_000115.5) | Silent (SNP) | VAF 207/419 reads (49%) | catalogued as COSV57521197; called by muse, mutect2, varscan2
- EFTUD2 | c.2124G>T p.T708= | Silent (SNP) | VAF 118/295 reads (40%) | called by muse, mutect2, varscan2
- EHMT1 | c.2181C>T p.L727= | Silent (SNP) | VAF 27/307 reads (9%) | catalogued as rs377163037; ClinVar: likely benign; called by muse, mutect2
- EVPL | c.2670C>T p.L890= | Silent (SNP) | VAF 30/266 reads (11%) | called by muse, varscan2
- FAM110D | c.258C>T p.F86= | Silent (SNP) | VAF 165/433 reads (38%) | called by muse, mutect2, varscan2
- FAT2 | c.576G>A p.E192= | Silent (SNP) | VAF 20/675 reads (3%) | called by muse, mutect2
- FAT4 | c.13251C>T p.C4417= | Silent (SNP) | VAF 145/319 reads (45%) | called by muse, mutect2, varscan2
- FBXW10 | c.1176G>C p.L392= | Silent (SNP) | VAF 8/160 reads (5%) | called by muse, mutect2
- FCAMR | c.1534C>T p.L512= (on ENST00000324852 / NM_001170631.2; = p.L244= on NM_032029.4) | Silent (SNP) | VAF 24/804 reads (3%) | called by muse, mutect2
- FMR1NB | c.234C>T p.I78= | Silent (SNP) | VAF 11/257 reads (4%) | called by muse, mutect2
- FNBP1L | c.1131C>T p.F377= | Silent (SNP) | VAF 19/242 reads (8%) | called by muse, mutect2
- FSCN3 | c.804C>T p.L268= | Silent (SNP) | VAF 12/306 reads (4%) | called by muse, mutect2
- GNB3 | c.237G>A p.L79= | Silent (SNP) | VAF 30/378 reads (8%) | called by muse, mutect2
- GPD1 | c.150G>A p.L50= | Silent (SNP) | VAF 15/370 reads (4%) | called by muse, mutect2
- GPR156 | c.291C>T p.L97= | Silent (SNP) | VAF 21/345 reads (6%) | catalogued as rs1287024519, COSV100251489; called by muse, mutect2
- GPR62 | c.612G>C p.L204= | Silent (SNP) | VAF 42/598 reads (7%) | catalogued as COSV59054689; called by muse, mutect2
- GTF2E2 | c.339C>G p.L113= | Silent (SNP) | VAF 85/264 reads (32%) | called by muse, mutect2, varscan2
- HAPLN1 | c.342G>C p.L114= | Silent (SNP) | VAF 350/532 reads (66%) | called by muse, mutect2, varscan2
- HELT | c.339G>T p.T113= | Silent (SNP) | VAF 34/489 reads (7%) | called by muse, mutect2
- HELZ | c.2004A>C p.G668= | Silent (SNP) | VAF 145/498 reads (29%) | called by muse, mutect2, varscan2
- HK1 | c.1437C>G p.L479= | Silent (SNP) | VAF 183/480 reads (38%) | called by muse, mutect2
- HSF1 | c.375G>A p.L125= | Silent (SNP) | VAF 98/1536 reads (6%) | catalogued as rs782221015, COSV101275173; called by muse, mutect2
- ID1 | c.402C>T p.G134= | Silent (SNP) | VAF 212/486 reads (44%) | called by muse, mutect2, varscan2
- IDUA | c.1161C>A p.L387= | Silent (SNP) | VAF 162/348 reads (47%) | called by muse, mutect2
- IFNA16 | c.399C>T p.A133= | Silent (SNP) | VAF 107/233 reads (46%) | catalogued as rs1241845133; called by muse, mutect2, varscan2
- INSIG1 | c.51G>T p.A17= | Silent (SNP) | VAF 178/395 reads (45%) | catalogued as COSV100453000; called by muse, mutect2, varscan2
- ISL1 | c.660C>T p.L220= | Silent (SNP) | VAF 30/651 reads (5%) | catalogued as COSV100045358; called by muse, mutect2
- ITGA8 | c.1188G>A p.L396= | Silent (SNP) | VAF 18/262 reads (7%) | called by muse, mutect2
- ITLN2 | c.261G>T p.G87= | Silent (SNP) | VAF 525/683 reads (77%) | called by muse, mutect2, varscan2
- KCNC2 | c.507C>T p.F169= | Silent (SNP) | VAF 47/534 reads (9%) | catalogued as rs960429937, COSV54365041, COSV54370311; called by muse, mutect2
- KCNG3 | c.255C>T p.F85= | Silent (SNP) | VAF 42/752 reads (6%) | catalogued as rs1285138887, COSV60148332; called by muse, mutect2
- KCNH5 | c.1167C>G p.L389= | Silent (SNP) | VAF 14/340 reads (4%) | called by muse, mutect2
- KCNK4 | c.546C>G p.L182= | Silent (SNP) | VAF 140/344 reads (41%) | catalogued as rs1417204846; called by muse, mutect2, varscan2
- KDM4B | c.1972C>T p.L658= | Silent (SNP) | VAF 76/408 reads (19%) | called by muse, mutect2, varscan2
- KHDRBS1 | c.855G>A p.G285= | Silent (SNP) | VAF 57/332 reads (17%) | catalogued as COSV56982765; called by muse, mutect2, varscan2
- KLHL29 | c.597G>A p.L199= | Silent (SNP) | VAF 28/884 reads (3%) | called by muse, mutect2
- KRTAP24-1 | c.753G>A p.L251= | Silent (SNP) | VAF 85/272 reads (31%) | catalogued as COSV61090125; called by muse, mutect2, varscan2
- LAMA4 | c.945C>T p.N315= (on ENST00000230538 / NM_001105206.3; = p.N308= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 130/272 reads (48%) | catalogued as rs782772720, COSV57899721; ClinVar: likely benign; called by muse, mutect2, varscan2
- LCE1E | c.159C>T p.G53= | Silent (SNP) | VAF 184/429 reads (43%) | catalogued as rs756254791; called by muse, mutect2, varscan2
- LCOR | c.1806G>A p.L602= | Silent (SNP) | VAF 12/324 reads (4%) | catalogued as COSV53715611; called by muse, mutect2
- LILRB5 | c.126G>A p.G42= | Silent (SNP) | VAF 33/505 reads (7%) | catalogued as rs1281493463, COSV100300577, COSV60261450; called by muse, mutect2
- LPIN2 | c.2253C>G p.V751= | Silent (SNP) | VAF 27/446 reads (6%) | called by muse, mutect2
- LRIT2 | c.765C>A p.I255= | Silent (SNP) | VAF 168/345 reads (49%) | called by muse, mutect2, varscan2
- LRP2 | c.3756G>C p.G1252= | Silent (SNP) | VAF 90/556 reads (16%) | called by muse, mutect2, varscan2
- LRRC24 | c.1455G>A p.A485= | Silent (SNP) | VAF 209/3348 reads (6%) | catalogued as rs1273209468; called by muse, mutect2
- LRRC7 | c.2829T>C p.L943= (on ENST00000651989 / NM_001370785.2; = p.L910= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 146/290 reads (50%) | called by muse, mutect2, varscan2
- MAN2A1 | c.2835G>A p.L945= | Silent (SNP) | VAF 12/294 reads (4%) | catalogued as COSV54854225; called by muse, mutect2
- MAP2 | c.4146C>T p.I1382= | Silent (SNP) | VAF 50/310 reads (16%) | catalogued as COSV52288891; called by muse, varscan2
- MAST4 | c.4198C>T p.L1400= (on ENST00000403625 / NM_001164664.2; = p.L1211= on NM_015183.3) | Silent (SNP) | VAF 42/901 reads (5%) | called by muse, mutect2
- MAT2B | c.672C>G p.V224= | Silent (SNP) | VAF 28/663 reads (4%) | catalogued as rs1472370288; called by muse, mutect2
- MBD6 | c.1344G>T p.G448= | Silent (SNP) | VAF 236/501 reads (47%) | called by muse, mutect2, varscan2
- MCM2 | c.735C>T p.A245= | Silent (SNP) | VAF 165/334 reads (49%) | called by muse, mutect2, varscan2
- MOGAT2 | c.720C>A p.G240= | Silent (SNP) | VAF 22/410 reads (5%) | called by muse, mutect2
- MPC2 | c.120A>T p.T40= | Silent (SNP) | VAF 76/158 reads (48%) | called by muse, mutect2, varscan2
- MRC1 | c.3981T>C p.G1327= | Silent (SNP) | VAF 200/413 reads (48%) | catalogued as rs1200579055; called by muse, mutect2, varscan2
- MTUS1 | c.3306G>A p.L1102= (on ENST00000262102 / NM_001363061.1; = p.L268= on NM_020749.4) | Silent (SNP) | VAF 36/293 reads (12%) | called by muse, mutect2, varscan2
- MYBPC2 | c.2487C>T p.V829= | Silent (SNP) | VAF 82/315 reads (26%) | called by muse, mutect2, varscan2
- NBEAL2 | c.3057C>G p.L1019= | Silent (SNP) | VAF 81/426 reads (19%) | catalogued as rs1321142562; called by muse, mutect2, varscan2
- NCAM1 | c.1413C>T p.A471= (on ENST00000316851 / NM_181351.5; = p.A461= on NM_000615.7) | Silent (SNP) | VAF 85/178 reads (48%) | catalogued as COSV57519869, COSV57522164; called by muse, mutect2, varscan2
- NEB | c.10485G>A p.K3495= | Silent (SNP) | VAF 28/461 reads (6%) | called by muse, mutect2
- NENF | c.156G>T p.L52= | Silent (SNP) | VAF 121/383 reads (32%) | called by muse, mutect2, varscan2
- NIPAL1 | c.1023G>T p.L341= | Silent (SNP) | VAF 136/271 reads (50%) | catalogued as COSV55006328; called by muse, mutect2, varscan2
- NKX3-1 | c.147G>A p.Q49= | Silent (SNP) | VAF 102/720 reads (14%) | called by muse, mutect2, varscan2
- NPAS4 | c.1470T>A p.T490= | Silent (SNP) | VAF 226/445 reads (51%) | called by muse, mutect2, varscan2
- NR0B1 | c.282G>A p.P94= | Silent (SNP) | VAF 13/348 reads (4%) | catalogued as COSV66763741, COSV66764402; called by muse, mutect2
- NRG1 | c.849G>T p.R283= (on ENST00000405005 / NM_013964.5; = p.R288= on NM_013956.5) | Silent (SNP) | VAF 326/450 reads (72%) | called by mutect2, varscan2
- NTRK3 | c.687C>T p.I229= | Silent (SNP) | VAF 98/299 reads (33%) | catalogued as rs866304195, COSV58122815; called by muse, mutect2, varscan2
- NUDT12 | c.1386C>G p.L462= | Silent (SNP) | VAF 77/229 reads (34%) | called by muse, mutect2, varscan2
- NUTM2A | c.987C>A p.V329= | Silent (SNP) | VAF 14/378 reads (4%) | called by muse, mutect2
- NUTM2D | c.771C>A p.V257= | Silent (SNP) | VAF 49/442 reads (11%) | called by muse, mutect2, varscan2
- OBSCN | c.17397C>T p.A5799= | Silent (SNP) | VAF 83/619 reads (13%) | called by muse, mutect2, varscan2
- OGDHL | c.1068G>T p.S356= | Silent (SNP) | VAF 239/458 reads (52%) | catalogued as rs562281972, COSV65104016; called by muse, mutect2, varscan2
- OR2G6 | c.555C>T p.I185= | Silent (SNP) | VAF 114/958 reads (12%) | catalogued as COSV58575052; called by muse, mutect2, varscan2
- OR2M5 | c.36C>T p.F12= | Silent (SNP) | VAF 67/1059 reads (6%) | catalogued as COSV63547154; called by muse, mutect2
- OR2T5 | c.54C>A p.L18= | Silent (SNP) | VAF 397/756 reads (53%) | catalogued as COSV63540469; called by muse, mutect2, varscan2
- OR4S2 | c.282G>T p.G94= | Silent (SNP) | VAF 200/408 reads (49%) | called by muse, mutect2
- OR52K2 | c.411C>A p.V137= | Silent (SNP) | VAF 27/371 reads (7%) | catalogued as COSV100355753; called by muse, mutect2
- OR5T3 | c.153G>A p.L51= | Silent (SNP) | VAF 21/395 reads (5%) | catalogued as COSV100282917, COSV57380033; called by muse, mutect2
- OR8G5 | c.555G>A p.L185= | Silent (SNP) | VAF 10/254 reads (4%) | called by muse, mutect2
- PAG1 | c.90C>T p.I30= | Silent (SNP) | VAF 43/568 reads (8%) | catalogued as rs751861984, COSV55062276; called by muse, mutect2
- PAX7 | c.1218C>A p.I406= | Silent (SNP) | VAF 252/516 reads (49%) | called by muse, mutect2, varscan2
- PCF11 | c.2626C>T p.L876= | Silent (SNP) | VAF 53/327 reads (16%) | called by muse, mutect2, varscan2
- PEAK1 | c.4659G>A p.V1553= | Silent (SNP) | VAF 112/294 reads (38%) | called by muse, mutect2
- PHKA2 | c.1284A>G p.R428= | Silent (SNP) | VAF 136/136 reads (100%) | called by muse, mutect2, varscan2
- PLEC | c.1767C>G p.L589= (on ENST00000322810 / NM_201380.4; = p.L479= on NM_000445.5) | Silent (SNP) | VAF 184/1567 reads (12%) | catalogued as rs1554719227, COSV59641645; called by muse, mutect2, varscan2
- PLXND1 | c.981C>T p.A327= | Silent (SNP) | VAF 261/531 reads (49%) | catalogued as rs1397305347; called by muse, mutect2, varscan2
- POGK | c.1497G>C p.L499= | Silent (SNP) | VAF 20/352 reads (6%) | called by muse, mutect2
- POLD1 | c.1992C>G p.L664= | Silent (SNP) | VAF 34/268 reads (13%) | called by muse, mutect2, varscan2
- PPP1R3D | c.894C>T p.F298= | Silent (SNP) | VAF 15/291 reads (5%) | catalogued as rs1242364009; called by muse, mutect2
- PRKAR1A | c.1053C>T p.D351= | Silent (SNP) | VAF 175/580 reads (30%) | catalogued as rs750774049; called by muse, mutect2, varscan2
- PROX1 | c.1863C>T p.I621= | Silent (SNP) | VAF 81/323 reads (25%) | called by muse, mutect2, varscan2
- PSMB3 | c.516G>T p.L172= | Silent (SNP) | VAF 148/431 reads (34%) | called by muse, mutect2, varscan2
- RTL1 | c.1632A>T p.L544= | Silent (SNP) | VAF 155/383 reads (40%) | called by muse, mutect2, varscan2
- RYR3 | c.11989T>C p.L3997= (on ENST00000389232; = p.L3998= on NM_001036.6) | Silent (SNP) | VAF 175/365 reads (48%) | catalogued as rs1377742527, COSV66779225; called by muse, mutect2, varscan2
- SCAF1 | c.2649C>T p.A883= | Silent (SNP) | VAF 31/520 reads (6%) | catalogued as rs1164395750; called by muse, mutect2
- SENP1 | c.516G>A p.K172= | Silent (SNP) | VAF 88/232 reads (38%) | called by muse, mutect2, varscan2
- SETBP1 | c.2616G>A p.G872= | Silent (SNP) | VAF 165/323 reads (51%) | called by muse, mutect2, varscan2
- SH3D21 | c.2208G>C p.V736= (on ENST00000453908 / NM_001162530.2; = p.V625= on NM_024676.5) | Silent (SNP) | VAF 29/436 reads (7%) | called by muse, mutect2
- SH3RF2 | c.1980C>T p.P660= | Silent (SNP) | VAF 169/542 reads (31%) | catalogued as rs867213169; called by muse, mutect2, varscan2
- SHROOM3 | c.5682G>A p.L1894= | Silent (SNP) | VAF 129/261 reads (49%) | catalogued as rs1293053602; called by muse, mutect2, varscan2
- SIX3 | c.261C>T p.F87= | Silent (SNP) | VAF 170/542 reads (31%) | catalogued as rs1279186542; called by muse, varscan2
- SLC25A42 | c.933C>A p.I311= | Silent (SNP) | VAF 31/325 reads (10%) | called by muse, mutect2
- SLC25A52 | c.873C>T p.I291= (on ENST00000672005; = p.I281= on NM_001034172.4) | Silent (SNP) | VAF 110/203 reads (54%) | catalogued as rs1202629150; called by muse, mutect2, varscan2
- SLC2A4RG | c.237G>A p.A79= | Silent (SNP) | VAF 206/395 reads (52%) | called by muse, mutect2, varscan2
- SLC35B2 | c.816C>T p.L272= | Silent (SNP) | VAF 170/337 reads (50%) | called by muse, mutect2, varscan2
- SLC4A7 | c.1284A>T p.A428= | Silent (SNP) | VAF 11/276 reads (4%) | called by muse, mutect2
- SLC8B1 | c.1656C>G p.L552= | Silent (SNP) | VAF 28/312 reads (9%) | catalogued as COSV52527355; called by muse, mutect2
- SMC6 | c.591C>T p.F197= | Silent (SNP) | VAF 77/353 reads (22%) | called by muse, mutect2, varscan2
- SOX3 | c.1224C>T p.G408= | Silent (SNP) | VAF 27/225 reads (12%) | called by muse, mutect2, varscan2
- SPAG17 | c.6363G>A p.L2121= | Silent (SNP) | VAF 97/257 reads (38%) | catalogued as COSV60471024; called by muse, mutect2, varscan2
63 further variants in this file (0 protein-altering or splice-affecting, 46 silent, 17 other) are not listed here.
